Somatic mutation profile of tumor specimen C3N-00321-01 (aliquot CPT0010260006) from CPTAC case C3N-00321, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G1; Age at diagnosis: 64.2 years (23,452 days).
Specimen C3N-00321-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 64de2ef5-d718-4c9d-920c-15a2c91bfbbf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00321-31 (Blood Derived Normal), aliquot CPT0010380002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/784b5686-a687-4bd6-a795-6fedf777a123

The open-access MAF lists 1,275 somatic variants for this specimen: 871 protein-altering or splice-affecting, 226 silent, 178 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 593, Silent 226, Frame Shift Del 177, Intron 97, Frame Shift Ins 31, Nonsense Mutation 29, 3'UTR 26, In Frame Del 17, RNA 16, 5'UTR 14, 3'Flank 13, Splice Site 12.

Variants (750 of 1,275; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASXL1 | c.1934del p.G645Vfs*58 | Frame Shift Del (DEL) | VAF 36/121 reads (30%) | hotspot (GDC flag); catalogued as rs750318549; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- B3GALT6 | c.588del p.R197Afs*81 | Frame Shift Del (DEL) | VAF 12/58 reads (21%) | catalogued as rs533071750, COSV55420617; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CCDC47 | c.1189C>T p.R397* | Nonsense Mutation (SNP) | VAF 28/114 reads (25%) | catalogued as rs1269750663, COSV99854157; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- CHST3 | c.533del p.G178Afs*38 | Frame Shift Del (DEL) | VAF 87/575 reads (15%) | catalogued as rs769540174; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- CNNM2 | c.117del p.I40Sfs*15 | Frame Shift Del (DEL) | VAF 15/159 reads (9%) | catalogued as rs1564803221; ClinVar: pathogenic; called by mutect2, pindel
- CTCF | c.610dup p.T204Nfs*26 | Frame Shift Ins (INS) | VAF 70/426 reads (16%) | catalogued as rs886041997; ClinVar: pathogenic; called by mutect2, varscan2
- DNAAF3 | c.997del p.D333Tfs*75 (on ENST00000524407 / NM_001256715.2; = p.D380Tfs*75 on NM_178837.4) | Frame Shift Del (DEL) | VAF 88/320 reads (28%) | catalogued as rs756430359; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- FBXW7 | c.1393C>T p.R465C (on ENST00000281708 / NM_001349798.2; = p.R385C on NM_018315.5) | Missense Mutation (SNP) | VAF 25/130 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867384286, COSV55891008, COSV55897912, COSV99654845; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FLCN | c.1285del p.H429Tfs*39 | Frame Shift Del (DEL) | VAF 40/153 reads (26%) | catalogued as rs80338682, CD023282, CM082680; ClinVar: pathogenic; called by mutect2, varscan2
- HAMP | c.166C>T p.R56* | Nonsense Mutation (SNP) | VAF 58/718 reads (8%) | catalogued as rs104894695, CM030043, COSV55885253, COSV55885498; ClinVar: pathogenic; called by muse, mutect2
- MAX | c.83A>G p.H28R | Missense Mutation (SNP) | VAF 90/483 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV52415800; called by muse, mutect2, varscan2
- MRPS22 | c.506G>A p.R169H (on ENST00000310776 / NM_001363893.1; = p.R170H on NM_020191.4) | Missense Mutation (SNP) | VAF 71/307 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs119478059, CM076316; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MTR | c.3518C>T p.P1173L | Missense Mutation (SNP) | VAF 48/242 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913578, CM961003; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MYH11 | c.5787-4707del | Intron (DEL) | VAF 31/288 reads (11%) | catalogued as rs747392139, COSV100257523; ClinVar: uncertain significance / benign / likely benign / likely pathogenic; called by mutect2, varscan2
- OPLAH | c.2608dup p.H870Pfs*92 | Frame Shift Ins (INS) | VAF 36/124 reads (29%) | catalogued as rs781956288; ClinVar: pathogenic; called by mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 18/72 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- RPE65 | c.1067dup p.N356Kfs*9 | Frame Shift Ins (INS) | VAF 44/212 reads (21%) | catalogued as rs281865520; ClinVar: not provided / pathogenic; called by mutect2, varscan2
- SCN4A | c.2015G>A p.R672H | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.067); catalogued as rs80338788, CM004140, COSV101438734; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TERT | c.2431C>T p.R811C | Missense Mutation (SNP) | VAF 71/288 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs199422301, CM076555, COSV57237635; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TYR | c.572del p.G191Dfs*35 | Frame Shift Del (DEL) | VAF 21/210 reads (10%) | catalogued as rs61754361, COSV54469089, COSV99633279; ClinVar: not provided / pathogenic; called by mutect2, pindel
- ABCA13 | c.10550G>A p.G3517E | Missense Mutation (SNP) | VAF 28/340 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99081670; called by muse, mutect2
- ABCA2 | c.4627C>T p.R1543C (on ENST00000614293; = p.R1513C on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/297 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs1277866366; called by muse, mutect2, varscan2
- ABCB9 | c.292A>G p.M98V | Missense Mutation (SNP) | VAF 66/530 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs766963390; called by muse, mutect2, varscan2
- ABCC11 | c.3395C>T p.P1132L | Missense Mutation (SNP) | VAF 50/158 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.747); catalogued as rs745724144; called by muse, mutect2, varscan2
- ABHD8 | c.58G>A p.A20T | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.041); catalogued as rs1382768097; called by muse, mutect2
- ACTA1 | c.121del p.R41Dfs*27 | Frame Shift Del (DEL) | VAF 93/233 reads (40%) | catalogued as CM034490; called by mutect2, varscan2
- ACVR1 | c.193G>A p.V65I | Missense Mutation (SNP) | VAF 90/371 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs370028017; called by muse, varscan2
- ADAMTS19 | c.1505A>G p.H502R | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99177058; called by muse, mutect2
- ADAMTSL5 | c.979del p.V327Wfs*101 | Frame Shift Del (DEL) | VAF 9/80 reads (11%) | catalogued as COSV100389290; called by mutect2, pindel
- ADCY3 | c.1085G>A p.R362Q | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1344400288; called by muse, mutect2
- ADCY7 | c.1956del p.T653Rfs*15 | Frame Shift Del (DEL) | VAF 29/112 reads (26%) | catalogued as COSV99576506; called by mutect2, pindel, varscan2
- ADGRA2 | c.3257del p.P1086Lfs*217 | Frame Shift Del (DEL) | VAF 20/94 reads (21%) | catalogued as rs1189742043; called by mutect2, pindel, varscan2
- ADPRH | c.410G>A p.C137Y | Missense Mutation (SNP) | VAF 38/556 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1308480086; called by muse, mutect2
- AIFM2 | c.947G>A p.R316Q | Missense Mutation (SNP) | VAF 46/278 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs750119679, COSV100325838; called by muse, mutect2
- AK9 | c.3625del p.R1209Gfs*39 | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | catalogued as rs778351035; called by mutect2, pindel
- ALS2 | c.973A>G p.M325V | Missense Mutation (SNP) | VAF 89/318 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs780945306; called by muse, mutect2, varscan2
- ANK1 | c.1282del p.A428Rfs*8 | Frame Shift Del (DEL) | VAF 118/464 reads (25%) | catalogued as CD971977; called by mutect2, pindel, varscan2
- ANKDD1B | c.704del p.X235_splice | Splice Site (DEL) | VAF 24/115 reads (21%) | catalogued as rs1389704893; called by mutect2, varscan2
- ANKFN1 | c.767G>A p.R256Q | Missense Mutation (SNP) | VAF 51/156 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.326); catalogued as rs752022371; called by muse, mutect2
- ANKLE2 | c.1000del p.R334Gfs*3 | Frame Shift Del (DEL) | VAF 14/176 reads (8%) | catalogued as COSV61708663; called by mutect2, pindel
- ANKRD34C | c.776C>T p.A259V | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs560579919; called by muse, mutect2, varscan2
- ANKRD40 | c.713A>T p.Y238F | Missense Mutation (SNP) | VAF 18/249 reads (7%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs765373793; called by muse, mutect2
- ANP32A | c.581A>G p.E194G | Missense Mutation (SNP) | VAF 16/250 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0.109); catalogued as COSV51189788; called by muse, mutect2
- AP3B2 | c.281A>G p.Y94C | Missense Mutation (SNP) | VAF 9/146 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1555468116; ClinVar: uncertain significance; called by muse, mutect2
- APC2 | c.4418del p.P1473Rfs*107 | Frame Shift Del (DEL) | VAF 13/56 reads (23%) | catalogued as rs1362621062; called by mutect2, pindel, varscan2
- ARHGAP23 | c.3047C>T p.T1016M | Missense Mutation (SNP) | VAF 44/245 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.608); catalogued as rs767269458; called by muse, mutect2, varscan2
- ARHGEF11 | c.922G>A p.D308N | Missense Mutation (SNP) | VAF 29/167 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.042); catalogued as rs1003135384; called by muse, mutect2, varscan2
- ASB1 | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 61/215 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs762122703, COSV52828544; called by muse, mutect2, varscan2
- ASCC3 | c.4553G>A p.R1518H | Missense Mutation (SNP) | VAF 106/394 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs148742449; called by muse, mutect2, varscan2
- ASCL4 | c.253C>T p.R85W | Missense Mutation (SNP) | VAF 93/346 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60817040; called by muse, mutect2, varscan2
- ASH1L | c.2134del p.R712Efs*23 | Frame Shift Del (DEL) | VAF 36/163 reads (22%) | catalogued as rs1558150870; called by mutect2, varscan2
- ASPHD2 | c.178G>A p.A60T | Missense Mutation (SNP) | VAF 16/147 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.552); catalogued as rs1337610242, COSV53219626; called by muse, mutect2, varscan2
- ATG14 | c.730A>G p.T244A | Missense Mutation (SNP) | VAF 41/449 reads (9%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.905); catalogued as rs144864735; called by muse, mutect2
- ATP1A3 | c.2668C>T p.R890W (on ENST00000545399 / NM_001256214.2; = p.R877W on NM_152296.5) | Missense Mutation (SNP) | VAF 30/494 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1568853525, COSV57490570; called by muse, mutect2
- ATP6V1E2 | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 61/238 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.299); catalogued as rs150480219, COSV104403651; called by muse, mutect2, varscan2
- BAAT | c.23C>A p.P8H | Missense Mutation (SNP) | VAF 22/258 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52290227; called by muse, mutect2
- BDP1 | c.3818C>T p.A1273V | Missense Mutation (SNP) | VAF 39/183 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as rs1335452738; called by muse, mutect2, varscan2
- BEND5 | c.40T>C p.Y14H | Missense Mutation (SNP) | VAF 67/278 reads (24%) | SIFT tolerated, low confidence (0.37); PolyPhen possibly damaging (0.86); catalogued as rs1164802876; called by muse, mutect2, varscan2
- BIRC6 | c.12497G>A p.R4166H | Missense Mutation (SNP) | VAF 88/339 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748782106; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.1790T>C p.L597P | Missense Mutation (SNP) | VAF 36/340 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.319); catalogued as rs755351947; called by muse, mutect2, varscan2
- BOC | c.2546G>A p.R849H | Missense Mutation (SNP) | VAF 17/233 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs571119647, COSV99847751; called by muse, mutect2
- BRICD5 | c.28C>T p.R10C | Missense Mutation (SNP) | VAF 20/259 reads (8%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as rs547524671, COSV100063822; called by muse, mutect2
- C12orf42 | c.1058C>T p.P353L | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.049); catalogued as rs762594015; called by muse, mutect2, varscan2
- C12orf57 | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 39/235 reads (17%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.034); catalogued as rs374751929; called by muse, mutect2, varscan2
- C2CD2 | c.597G>T p.E199D | Missense Mutation (SNP) | VAF 60/208 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.044); catalogued as COSV61600073; called by muse, mutect2, varscan2
- C3orf20 | c.1103C>T p.A368V | Missense Mutation (SNP) | VAF 79/337 reads (23%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs769972859; called by muse, mutect2, varscan2
- C4orf54 | c.2617G>A p.G873S | Missense Mutation (SNP) | VAF 29/298 reads (10%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as rs139641765, COSV72766931; called by muse, mutect2
- C5orf34 | c.679C>T p.P227S | Missense Mutation (SNP) | VAF 67/235 reads (29%) | SIFT tolerated (0.52); PolyPhen benign (0.011); catalogued as COSV60931878; called by muse, mutect2, varscan2
- C6 | c.2216C>T p.A739V | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as COSV99667401; called by muse, mutect2
- C8orf58 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 38/162 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs769696478, COSV51514782, COSV51515153; called by muse, mutect2, varscan2
- CAAP1 | c.571A>T p.I191F | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.165); catalogued as COSV61700397; called by muse, varscan2
- CACNA1A | c.1141C>T p.R381W | Missense Mutation (SNP) | VAF 45/189 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs773593740, COSV100801034, COSV64212946; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1H | c.635G>A p.R212H | Missense Mutation (SNP) | VAF 26/300 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755428172; called by muse, mutect2
- CACNA1I | c.1291C>T p.P431S | Missense Mutation (SNP) | VAF 81/283 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1489978770; called by muse, mutect2, varscan2
- CALCR | c.1027del p.M343* (on ENST00000649521 / NM_001164737.2; = p.M327* on NM_001742.4) | Frame Shift Del (DEL) | VAF 70/268 reads (26%) | catalogued as COSV104420925, COSV64008873; called by mutect2, pindel, varscan2
- CCDC178 | c.1415G>A p.R472Q | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as rs748481282; called by muse, mutect2
- CEACAM20 | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 76/354 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.835); catalogued as COSV100386923; called by muse, mutect2, varscan2
- CEL | c.2107del p.A703Pfs*4 (on ENST00000673714; = p.A700Pfs*4 on NM_001807.6) | Frame Shift Del (DEL) | VAF 23/186 reads (12%) | catalogued as rs1229199498; called by pindel, varscan2
- CELSR2 | c.2236C>T p.R746C | Missense Mutation (SNP) | VAF 54/229 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780995915, COSV54775709; called by muse, mutect2, varscan2
- CFP | c.848C>T p.T283M | Missense Mutation (SNP) | VAF 42/156 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.092); catalogued as rs1325258357, COSV55950951; called by muse, mutect2, varscan2
- CHAT | c.413C>T p.P138L | Missense Mutation (SNP) | VAF 60/432 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.413); catalogued as rs557059182, COSV60321532, COSV60324539; called by muse, mutect2, varscan2
- CHD6 | c.4177G>A p.A1393T | Missense Mutation (SNP) | VAF 26/382 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.125); catalogued as rs147954398; called by muse, mutect2
- CHRNA3 | c.814_816del p.K272del | In Frame Del (DEL) | VAF 31/224 reads (14%) | catalogued as rs1423035143; called by mutect2, pindel, varscan2
- CHST12 | c.1049C>T p.A350V | Missense Mutation (SNP) | VAF 37/138 reads (27%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.795); catalogued as rs957160573; called by muse, mutect2, varscan2
- CNTNAP5 | c.2841G>T p.K947N | Missense Mutation (SNP) | VAF 71/285 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.265); catalogued as COSV70498767; called by muse, mutect2, varscan2
- CORO1A | c.20G>A p.R7H | Missense Mutation (SNP) | VAF 41/432 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54631241; called by muse, mutect2
- CPNE4 | c.548G>A p.R183H | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs759688830, COSV101456761; called by muse, mutect2, varscan2
- CPSF1 | c.1951G>A p.V651M | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.72); catalogued as rs782245666; called by muse, mutect2
- CREB3L3 | c.746G>A p.R249Q | Missense Mutation (SNP) | VAF 145/574 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99313991; called by muse, varscan2
- CRYGA | c.476del p.G159Vfs*9 | Frame Shift Del (DEL) | VAF 10/117 reads (9%) | catalogued as rs762650691; called by mutect2, pindel
- CSMD3 | c.7996T>C p.S2666P (on ENST00000297405 / NM_001363185.1; = p.S2562P on NM_052900.3) | Missense Mutation (SNP) | VAF 21/292 reads (7%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.999); catalogued as COSV52201294; called by muse, mutect2
- CSPG4 | c.978dup p.L327Afs*62 | Frame Shift Ins (INS) | VAF 38/119 reads (32%) | catalogued as rs1400351952; called by mutect2, pindel, varscan2
- CTNS | c.631C>T p.H211Y | Missense Mutation (SNP) | VAF 33/564 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV50440983; called by muse, mutect2
- CYB5R4 | c.741del p.E248Rfs*12 | Frame Shift Del (DEL) | VAF 22/63 reads (35%) | catalogued as rs745836350; called by mutect2, varscan2
- CYLC2 | c.980C>T p.A327V | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.201); catalogued as rs1245398013; called by muse, mutect2, varscan2
- CYP1B1 | c.763C>T p.R255C | Missense Mutation (SNP) | VAF 157/578 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs886055998, COSV53191240; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CYP1B1 | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 38/347 reads (11%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.577); catalogued as COSV53190737; called by muse, mutect2, varscan2
- CYP4B1 | c.1400C>T p.T467I | Missense Mutation (SNP) | VAF 36/160 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.012); catalogued as rs773663866; called by muse, mutect2, varscan2
- CYTIP | c.871del p.D291Mfs*4 | Frame Shift Del (DEL) | VAF 61/281 reads (22%) | catalogued as COSV51633512; called by mutect2, pindel, varscan2
- DAPK3 | c.1018C>T p.R340C | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as rs1217983026; called by muse, mutect2
- DCAF6 | c.119G>A p.R40K | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.699); catalogued as COSV56581749; called by muse, mutect2, varscan2
- DDX31 | c.1376C>T p.A459V | Missense Mutation (SNP) | VAF 99/377 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs370929391; called by muse, mutect2, varscan2
- DDX42 | c.1586A>G p.H529R | Missense Mutation (SNP) | VAF 64/227 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1214321890, COSV63790928; called by muse, mutect2, varscan2
- DEUP1 | c.588del p.K196Nfs*4 | Frame Shift Del (DEL) | VAF 12/117 reads (10%) | catalogued as rs929547033; called by mutect2, pindel, varscan2
- DHX57 | c.3190G>A p.V1064M | Missense Mutation (SNP) | VAF 30/328 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs149500475; called by muse, mutect2
- DHX57 | c.2195del p.L732Wfs*7 | Frame Shift Del (DEL) | VAF 12/106 reads (11%) | catalogued as rs749610132; called by mutect2, varscan2
- DIDO1 | c.4854del p.W1619Gfs*245 | Frame Shift Del (DEL) | VAF 38/166 reads (23%) | catalogued as COSV56622557; called by mutect2, pindel, varscan2
- DIP2A | c.3320G>A p.R1107Q | Missense Mutation (SNP) | VAF 47/226 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.386); catalogued as rs767678653; called by muse, mutect2, varscan2
- DIPK1B | c.997C>T p.R333C | Missense Mutation (SNP) | VAF 31/143 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); catalogued as rs528228625; called by muse, mutect2, varscan2
- DIS3L2 | c.2005A>G p.M669V | Missense Mutation (SNP) | VAF 18/230 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.895); catalogued as rs1553550940; ClinVar: uncertain significance; called by muse, mutect2
- DIXDC1 | c.1378C>T p.R460* (on ENST00000440460 / NM_001037954.4; = p.R249* on NM_033425.4) | Nonsense Mutation (SNP) | VAF 21/256 reads (8%) | catalogued as rs782163999; called by muse, mutect2
- DNAAF5 | c.1302G>T p.E434D | Missense Mutation (SNP) | VAF 43/374 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.042); catalogued as COSV52415605; called by muse, mutect2, varscan2
- DNAH7 | c.2294C>A p.P765H | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs984399130; called by muse, mutect2, varscan2
- DNHD1 | c.1564C>T p.R522C | Missense Mutation (SNP) | VAF 112/413 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.055); catalogued as rs755744999, COSV54440769, COSV54443485; called by muse, mutect2, varscan2
- DNM3 | c.2300G>A p.R767H (on ENST00000355305 / NM_001350206.2; = p.R761H on NM_015569.5) | Missense Mutation (SNP) | VAF 37/141 reads (26%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs779486284, COSV100798099, COSV100798567; called by muse, mutect2
- DNMBP | c.1154C>T p.P385L | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs143875074; called by muse, mutect2
- DNMT3A | c.176del p.P59Rfs*13 | Frame Shift Del (DEL) | VAF 17/95 reads (18%) | catalogued as COSV53040261; called by mutect2, pindel, varscan2
- DOP1A | c.2321G>A p.R774H | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs986224867; called by muse, mutect2, varscan2
- DRD1 | c.155G>A p.R52Q | Missense Mutation (SNP) | VAF 33/324 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1334164789, COSV99062300; called by muse, mutect2, varscan2
- DRGX | c.390G>T p.K130N | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.991); catalogued as COSV100938403; called by muse, mutect2, varscan2
- EAF1 | c.41A>G p.H14R | Missense Mutation (SNP) | VAF 53/209 reads (25%) | SIFT tolerated (1); PolyPhen probably damaging (0.987); catalogued as rs748304883; called by muse, mutect2, varscan2
- EEF2 | c.91G>A p.G31S | Missense Mutation (SNP) | VAF 61/210 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100500806; called by muse, mutect2, varscan2
- EFHD1 | c.376del p.Q126Rfs*6 | Frame Shift Del (DEL) | VAF 32/142 reads (23%) | catalogued as rs760712775, COSV51135066; called by mutect2, varscan2
- EGR4 | c.79del p.E27Sfs*127 | Frame Shift Del (DEL) | VAF 14/130 reads (11%) | catalogued as rs1254850903; called by mutect2, pindel, varscan2
- EIF2S3 | c.344C>T p.T115M | Missense Mutation (SNP) | VAF 19/165 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as rs1246329689, COSV53407790; called by muse, mutect2, varscan2
- ELP6 | c.40G>A p.D14N | Missense Mutation (SNP) | VAF 27/246 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.771); catalogued as rs1271210450; called by muse, mutect2, varscan2
- EMILIN3 | c.1373dup p.M458Ifs*34 | Frame Shift Ins (INS) | VAF 11/80 reads (14%) | catalogued as COSV60037225; called by mutect2, pindel, varscan2
- ENC1 | c.305T>C p.L102P | Missense Mutation (SNP) | VAF 74/279 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs267600684; called by muse, mutect2, varscan2
- EPHA1 | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 78/305 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV51970732; called by muse, mutect2, varscan2
- ERCC2 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 48/163 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs375415853; called by muse, mutect2, varscan2
- ERICH6B | c.950del p.K317Rfs*18 | Frame Shift Del (DEL) | VAF 19/115 reads (17%) | catalogued as rs754232917, COSV100074795; called by mutect2, varscan2
- ESRP1 | c.790C>T p.R264* | Nonsense Mutation (SNP) | VAF 59/251 reads (24%) | catalogued as rs1236801174, COSV64410337; called by muse, mutect2, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 66/260 reads (25%) | catalogued as rs775950025; called by mutect2, varscan2
- EXOC6B | c.2000C>T p.A667V | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.989); catalogued as rs779061450; called by muse, mutect2, varscan2
- EZHIP | c.787G>A p.A263T | Missense Mutation (SNP) | VAF 47/241 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.031); catalogued as rs1557318797; called by muse, mutect2, varscan2
- FADS3 | c.637C>T p.H213Y | Missense Mutation (SNP) | VAF 12/125 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as COSV99605480; called by muse, mutect2
- FAM163A | c.31G>A p.G11R | Missense Mutation (SNP) | VAF 143/379 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1193267004, COSV59203867; called by muse, mutect2, varscan2
- FAM83F | c.1161del p.V388Wfs*9 | Frame Shift Del (DEL) | VAF 27/96 reads (28%) | catalogued as rs1569234985; called by mutect2, pindel, varscan2
- FAM9A | c.477del p.K159Nfs*3 | Frame Shift Del (DEL) | VAF 12/40 reads (30%) | catalogued as rs748967872; called by mutect2, varscan2
- FAT4 | c.1166C>T p.A389V | Missense Mutation (SNP) | VAF 30/188 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV67901676; called by muse, mutect2, varscan2
- FBLL1 | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.49); catalogued as rs1355631660; called by muse, mutect2, varscan2
- FBRS | c.1333dup p.R445Pfs*7 (on ENST00000287468; = p.R965Pfs*7 on NM_001105079.3) | Frame Shift Ins (INS) | VAF 32/125 reads (26%) | catalogued as rs776673463; called by mutect2, pindel, varscan2
- FBXL12 | c.487G>A p.A163T | Missense Mutation (SNP) | VAF 37/173 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.422); catalogued as rs770789822; called by muse, mutect2, varscan2
- FBXO41 | c.509C>T p.T170M | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.639); catalogued as rs1359205001; called by muse, mutect2, varscan2
- FCRL1 | c.95G>A p.S32N | Missense Mutation (SNP) | VAF 14/218 reads (6%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV100839680; called by muse, mutect2
- FGF22 | c.367G>A p.G123S | Missense Mutation (SNP) | VAF 67/330 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs140007905; called by muse, mutect2, varscan2
- FGF23 | c.701C>T p.T234M | Missense Mutation (SNP) | VAF 128/500 reads (26%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs1414743251; called by muse, mutect2, varscan2
- FHOD3 | c.1005del p.S336Vfs*138 | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | catalogued as rs777980924; called by mutect2, pindel
- FIGNL2 | c.1576del p.A526Lfs*164 | Frame Shift Del (DEL) | VAF 21/192 reads (11%) | catalogued as rs1330579577; called by mutect2, pindel
- FKBP8 | c.1023G>A p.T341= (on ENST00000222308 / NM_001308373.2; = p.T342= on NM_012181.5) | Splice Region (SNP) | VAF 9/129 reads (7%) | catalogued as rs1382563520, COSV55893257; called by muse, mutect2
- FLG | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 57/183 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV64246182; called by muse, mutect2, varscan2
- FOCAD | c.5212G>T p.A1738S | Missense Mutation (SNP) | VAF 22/202 reads (11%) | SIFT tolerated (0.79); PolyPhen benign (0.024); catalogued as rs1247100798; called by muse, mutect2
- FRMD3 | c.1474G>A p.A492T | Missense Mutation (SNP) | VAF 37/331 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0.051); catalogued as rs765203567, COSV104409716; called by muse, mutect2, varscan2
- FRMD4A | c.1439G>A p.R480H | Missense Mutation (SNP) | VAF 43/377 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.909); catalogued as rs752187173, COSV52732144; called by muse, mutect2, varscan2
- FRMPD1 | c.4040C>T p.P1347L | Missense Mutation (SNP) | VAF 20/273 reads (7%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs150024267; called by muse, mutect2
- FZD8 | c.1364C>T p.A455V | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.464); catalogued as COSV65968154; called by muse, mutect2
- GABRG1 | c.792dup p.D265* | Frame Shift Ins (INS) | VAF 16/56 reads (29%) | catalogued as rs772301203; called by mutect2, varscan2
- GAGE2A | c.25T>C p.Y9H | Missense Mutation (SNP) | VAF 130/4534 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1557130266; called by muse, mutect2
- GALK1 | c.592G>A p.A198T | Missense Mutation (SNP) | VAF 26/328 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.096); catalogued as rs757213297, COSV56689901; called by muse, mutect2
- GAS2L1 | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.535); catalogued as rs1188585936, COSV53332057; called by muse, mutect2, varscan2
- GATA6 | c.1618G>T p.G540W | Missense Mutation (SNP) | VAF 13/363 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV52526105; called by muse, mutect2
- GDF7 | c.682del p.R228Afs*41 | Frame Shift Del (DEL) | VAF 32/82 reads (39%) | catalogued as rs761897305; called by mutect2, varscan2
- GIPC3 | c.380C>T p.T127M | Missense Mutation (SNP) | VAF 37/128 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1017753310, COSV59258261; called by muse, mutect2, varscan2
- GLO1 | c.167C>T p.T56M | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.902); catalogued as rs150725457; called by muse, mutect2, varscan2
- GPR158 | c.599G>A p.R200H | Missense Mutation (SNP) | VAF 19/216 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.511); catalogued as rs1197032663; called by muse, mutect2
- GPR3 | c.250G>A p.V84M | Missense Mutation (SNP) | VAF 66/236 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.063); catalogued as rs150824796; called by muse, mutect2, varscan2
- GPR32 | c.1063dup p.R355Pfs*? | Frame Shift Ins (INS) | VAF 19/83 reads (23%) | catalogued as rs751525642; called by mutect2, pindel, varscan2
- GPR62 | c.322G>A p.A108T | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.473); catalogued as rs1353935837; called by muse, mutect2, varscan2
- GPRC5B | c.1042G>A p.A348T | Missense Mutation (SNP) | VAF 11/210 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.141); catalogued as rs1307485278; called by muse, mutect2
- GRID1 | c.2455G>A p.A819T | Missense Mutation (SNP) | VAF 20/284 reads (7%) | SIFT tolerated (0.64); PolyPhen benign (0.02); catalogued as rs781493433; called by muse, mutect2
- GRID1 | c.527G>A p.R176H | Missense Mutation (SNP) | VAF 18/204 reads (9%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.997); catalogued as rs778297585, COSV60019372; called by muse, mutect2
- GRIK1 | c.1099-2A>G p.X367_splice | Splice Site (SNP) | VAF 15/63 reads (24%) | catalogued as COSV58710927; called by muse, mutect2, varscan2
- GRIK3 | c.2192C>T p.T731M | Missense Mutation (SNP) | VAF 74/270 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.895); catalogued as rs572107668; called by muse, mutect2, varscan2
- GRIP2 | c.3302C>T p.A1101V (on ENST00000619221; = p.A1004V on NM_001080423.4) | Missense Mutation (SNP) | VAF 21/152 reads (14%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.733); catalogued as rs367805938; called by muse, mutect2, varscan2
- GRIPAP1 | c.1364G>A p.R455H | Missense Mutation (SNP) | VAF 26/376 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs782656835, COSV64552872; called by muse, mutect2
- GRM3 | c.958G>A p.A320T | Missense Mutation (SNP) | VAF 75/257 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1231023450, COSV64468709; called by muse, mutect2, varscan2
- GRM8 | c.293T>C p.L98P | Missense Mutation (SNP) | VAF 93/342 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100285837; called by muse, mutect2, varscan2
- GSE1 | c.1094G>A p.R365H | Missense Mutation (SNP) | VAF 173/648 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.472); catalogued as rs527940310; called by muse, mutect2, varscan2
- GTF2IRD2 | c.2411C>T p.A804V | Missense Mutation (SNP) | VAF 58/710 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.028); catalogued as COSV63100231; called by muse, mutect2
- GTF3C3 | c.389G>A p.R130H | Missense Mutation (SNP) | VAF 60/234 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs1246832442; called by muse, varscan2
- HAND2 | c.247del p.V83Cfs*16 | Frame Shift Del (DEL) | VAF 11/47 reads (23%) | catalogued as CM105646; called by mutect2, varscan2
- HDAC4 | c.2498A>G p.K833R | Missense Mutation (SNP) | VAF 133/472 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.048); catalogued as COSV61872326; called by muse, mutect2, varscan2
- HDAC5 | c.2793del p.I932Lfs*14 | Frame Shift Del (DEL) | VAF 16/166 reads (10%) | catalogued as COSV52242263; called by mutect2, pindel
- HECTD4 | c.1447C>T p.R483W | Missense Mutation (SNP) | VAF 25/159 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101108412; called by muse, mutect2, varscan2
- HEYL | c.494C>T p.T165M | Missense Mutation (SNP) | VAF 48/200 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.018); catalogued as rs368302386; called by muse, mutect2, varscan2
- HMGN5 | c.534del p.G179Vfs*48 | Frame Shift Del (DEL) | VAF 4/37 reads (11%) | catalogued as rs1556033122; called by pindel, varscan2
- HMX3 | c.68del p.P23Hfs*100 | Frame Shift Del (DEL) | VAF 6/32 reads (19%) | catalogued as rs779589617; called by mutect2, varscan2
- HOXA1 | c.521C>T p.A174V | Missense Mutation (SNP) | VAF 22/396 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.236); catalogued as COSV56067843; called by muse, mutect2
- HOXC11 | c.784C>T p.R262W | Missense Mutation (SNP) | VAF 36/424 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54532136; called by muse, mutect2
- HPS1 | c.1727C>T p.A576V | Missense Mutation (SNP) | VAF 49/536 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.318); catalogued as COSV57266914; called by muse, mutect2
- HPSE2 | c.686G>A p.R229H | Missense Mutation (SNP) | VAF 90/371 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs373252593, COSV100984811; called by muse, mutect2, varscan2
- HSBP1 | c.218C>T p.T73M | Missense Mutation (SNP) | VAF 60/170 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.387); catalogued as COSV101419156; called by muse, varscan2
- HSD17B4 | c.1764del p.F588Lfs*69 (on ENST00000414835 / NM_001199291.3; = p.F563Lfs*69 on NM_000414.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 19/135 reads (14%) | catalogued as COSV99819972; called by mutect2, pindel, varscan2
- HSPG2 | c.4648C>T p.R1550C | Missense Mutation (SNP) | VAF 38/462 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1317669197, CM065277; called by muse, mutect2
- IARS1 | c.2993G>A p.R998H | Missense Mutation (SNP) | VAF 45/179 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs1480100605; called by mutect2, varscan2
- IFNA13 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 23/165 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.215); catalogued as rs1164592178, COSV71924451; called by muse, mutect2, varscan2
- IGHV3-48 | c.110T>C p.L37P | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as rs782731316; called by muse, mutect2, varscan2
- IGSF3 | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 70/250 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs754395956; called by muse, mutect2, varscan2
- IL17A | c.400C>T p.R134W | Missense Mutation (SNP) | VAF 30/387 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs764987987, COSV100391392; called by muse, mutect2
- IL25 | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 70/277 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs199992202; called by muse, mutect2, varscan2
- IL27 | c.637G>T p.V213F | Missense Mutation (SNP) | VAF 92/360 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.019); catalogued as rs753219380, COSV60491613; called by muse, varscan2
- INPP5F | c.1417G>A p.A473T | Missense Mutation (SNP) | VAF 46/155 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as rs527761396; called by muse, mutect2, varscan2
- INPP5F | c.2824_2826del p.S942del | In Frame Del (DEL) | VAF 58/218 reads (27%) | catalogued as rs780782328; called by mutect2, pindel, varscan2
- INSM2 | c.1444G>A p.A482T | Missense Mutation (SNP) | VAF 109/481 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); catalogued as COSV99355791; called by muse, mutect2, varscan2
- INSR | c.1837A>G p.I613V | Missense Mutation (SNP) | VAF 18/324 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs1218016172; called by muse, mutect2
- ITGAE | c.2012C>T p.A671V | Missense Mutation (SNP) | VAF 47/156 reads (30%) | SIFT tolerated (0.81); PolyPhen benign (0.153); catalogued as rs147766404; called by muse, mutect2, varscan2
- ITPRID2 | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 52/302 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs1271328690; called by muse, mutect2, varscan2
- KAT6A | c.4870G>A p.V1624I | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.156); catalogued as rs144720569; called by muse, mutect2, varscan2
- KCNA1 | c.47C>T p.P16L | Missense Mutation (SNP) | VAF 64/245 reads (26%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.006); catalogued as rs1360223867; called by muse, varscan2
- KCNA10 | c.1066C>T p.R356C | Missense Mutation (SNP) | VAF 96/409 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768535829, COSV63904462; called by muse, mutect2, varscan2
- KCNH2 | c.2785del p.E929Rfs*45 | Frame Shift Del (DEL) | VAF 17/151 reads (11%) | catalogued as CD097541; called by mutect2, pindel, varscan2
- KCNJ11 | c.898G>A p.A300T | Missense Mutation (SNP) | VAF 28/451 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100379245; called by muse, mutect2
- KCNV1 | c.412C>T p.Q138* | Nonsense Mutation (SNP) | VAF 8/168 reads (5%) | catalogued as COSV104397962; called by muse, mutect2
- KDM4B | c.1400C>T p.P467L | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs767545488; called by muse, mutect2
- KDM5C | c.3088C>T p.R1030W | Missense Mutation (SNP) | VAF 29/311 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as rs782388435; called by muse, mutect2
- KDM6B | c.1874C>T p.P625L | Missense Mutation (SNP) | VAF 36/180 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.024); catalogued as rs112251890; called by muse, mutect2, varscan2
- KIAA1217 | c.4622C>T p.T1541M | Missense Mutation (SNP) | VAF 31/275 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs148213717; called by muse, mutect2, varscan2
- KIAA2012 | c.2836_2838del p.E946del | In Frame Del (DEL) | VAF 88/346 reads (25%) | catalogued as rs1263167184; called by mutect2, pindel, varscan2
- KIF22 | c.1009G>A p.A337T | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.842); catalogued as rs770987085; called by muse, mutect2, varscan2
- KIF26B | c.5779G>A p.G1927S | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.557); catalogued as rs765887032; called by muse, mutect2, varscan2
- KLHL10 | c.1567G>A p.E523K | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as COSV53175412; called by muse, mutect2
- KPRP | c.969del p.K324Sfs*47 | Frame Shift Del (DEL) | VAF 30/241 reads (12%) | catalogued as COSV64221091, COSV64221342; called by mutect2, pindel, varscan2
- KRT17 | c.770G>A p.R257H | Missense Mutation (SNP) | VAF 34/390 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.749); catalogued as rs200256057, COSV60860104, COSV60860584; called by muse, mutect2
- LAIR1 | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 74/264 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as rs1160864207; called by muse, mutect2, varscan2
- LAMP3 | c.233C>T p.A78V | Missense Mutation (SNP) | VAF 47/334 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.022); catalogued as rs114675283; called by muse, mutect2, varscan2
- LIPE | c.2077C>T p.R693C | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1166099993; called by muse, mutect2, varscan2
- LPIN1 | c.730G>A p.G244S | Missense Mutation (SNP) | VAF 38/444 reads (9%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as rs367859334; called by muse, mutect2
- LRRC24 | c.262G>A p.A88T | Missense Mutation (SNP) | VAF 22/163 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.098); catalogued as rs894207176, COSV52770579; called by muse, mutect2, varscan2
- LRRC56 | c.218C>T p.T73M | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs749620469, COSV54240645; called by muse, mutect2, varscan2
- LRRK2 | c.2129del p.N710Mfs*2 | Frame Shift Del (DEL) | VAF 66/250 reads (26%) | catalogued as COSV54153441; called by mutect2, pindel, varscan2
- LYST | c.6078C>A p.Y2026* | Nonsense Mutation (SNP) | VAF 28/157 reads (18%) | catalogued as rs80338660, CM021561, COSV67707063, COSV67714717; called by muse, mutect2, varscan2
- LZTS2 | c.944C>T p.P315L | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.296); catalogued as rs747208035, COSV64652368; called by muse, mutect2, varscan2
- MAB21L2 | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 22/210 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as COSV58262662; called by muse, mutect2, varscan2
- MAGEL2 | c.2224C>T p.R742C | Missense Mutation (SNP) | VAF 48/179 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.917); catalogued as rs761568970, COSV100045670, COSV58568250; called by muse, mutect2, varscan2
- MAN1B1 | c.1609G>A p.V537I | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.236); catalogued as rs761928483, COSV100857462; called by muse, mutect2, varscan2
- MAP10 | c.1448A>G p.K483R | Missense Mutation (SNP) | VAF 92/350 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.013); catalogued as COSV69363675; called by muse, mutect2, varscan2
- MATN4 | c.1219C>T p.R407C (on ENST00000372754; = p.R366C on NM_003833.4) | Missense Mutation (SNP) | VAF 9/93 reads (10%) | PolyPhen probably damaging (0.93); catalogued as rs745778874; called by mutect2, varscan2
- MCF2L2 | c.1057G>A p.V353M | Missense Mutation (SNP) | VAF 61/268 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.479); catalogued as rs774137199, COSV61062538; called by muse, mutect2, varscan2
- MDGA2 | c.169C>T p.R57C | Missense Mutation (SNP) | VAF 18/288 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.833); catalogued as rs947844781, COSV101229674; called by muse, mutect2
- MDN1 | c.16142G>A p.R5381H | Missense Mutation (SNP) | VAF 81/276 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs774329090, COSV65517410; called by muse, mutect2, varscan2
- MED25 | c.602del p.P201Rfs*13 | Frame Shift Del (DEL) | VAF 36/209 reads (17%) | catalogued as rs748546983; ClinVar: uncertain significance; called by mutect2, varscan2
- MEGF8 | c.2953T>C p.Y985H (on ENST00000251268 / NM_001271938.2; = p.Y918H on NM_001410.3) | Missense Mutation (SNP) | VAF 17/252 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs1051196312; called by muse, mutect2
- MELTF | c.1092del p.Y365Tfs*54 | Frame Shift Del (DEL) | VAF 20/140 reads (14%) | catalogued as rs748010566; called by mutect2, pindel, varscan2
- MEX3C | c.1271C>T p.A424V | Missense Mutation (SNP) | VAF 53/204 reads (26%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.883); catalogued as rs764461748, COSV68530629; called by muse, mutect2, varscan2
- MEX3D | c.1679C>T p.T560M | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.379); catalogued as rs538022731; called by muse, varscan2
- MGAT1 | c.1154G>A p.R385Q | Missense Mutation (SNP) | VAF 56/227 reads (25%) | PolyPhen probably damaging (0.988); catalogued as rs746679758; called by muse, mutect2, varscan2
- MOBP | c.404G>A p.R135H (on ENST00000420739; = p.R159H on NM_001278322.2) | Missense Mutation (SNP) | VAF 20/160 reads (13%) | PolyPhen possibly damaging (0.796); catalogued as rs1216228772; called by muse, varscan2
- MPP2 | c.376-3del | Splice Region (DEL) | VAF 23/107 reads (21%) | catalogued as rs769731446; called by mutect2, varscan2
- MRPL38 | c.771del p.F258Sfs*54 | Frame Shift Del (DEL) | VAF 16/71 reads (23%) | catalogued as rs758439223; called by mutect2, pindel, varscan2
- MTCL1 | c.1687del p.R563Gfs*5 (on ENST00000306329 / NM_001378206.1; = p.R203Gfs*5 on NM_015210.4) | Frame Shift Del (DEL) | VAF 15/155 reads (10%) | catalogued as rs753016620; called by mutect2, pindel, varscan2
- MTMR3 | c.3143A>G p.Q1048R | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs755422050; called by muse, mutect2
- MTX1 | c.22del p.R8Afs*110 | Frame Shift Del (DEL) | VAF 20/67 reads (30%) | catalogued as rs755845788, COSV57426587; called by mutect2, pindel, varscan2
- MUC13 | c.264del p.I89* | Frame Shift Del (DEL) | VAF 40/188 reads (21%) | catalogued as COSV60699158; called by mutect2, pindel, varscan2
- MUC16 | c.40192C>T p.R13398C | Missense Mutation (SNP) | VAF 44/179 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); catalogued as rs764584308, COSV66690430; called by muse, mutect2, varscan2
- MUC19 | c.461del p.K154Sfs*87 | Frame Shift Del (DEL) | VAF 23/76 reads (30%) | catalogued as rs537060918; called by mutect2, varscan2
- MXRA5 | c.6355C>T p.R2119C | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); catalogued as COSV54234496; called by muse, mutect2, varscan2
- MYBBP1A | c.2659C>T p.R887W | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs200573392; called by muse, mutect2, varscan2
- MYO15A | c.8428G>T p.G2810C | Missense Mutation (SNP) | VAF 73/293 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV52755190; called by muse, mutect2, varscan2
- MYORG | c.1745C>T p.A582V | Missense Mutation (SNP) | VAF 51/165 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV99898838; called by muse, mutect2, varscan2
- NACC1 | c.212C>T p.A71V | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.154); catalogued as rs779116546, COSV52835431; called by muse, mutect2, varscan2
- NBR1 | c.1897A>G p.I633V | Missense Mutation (SNP) | VAF 48/178 reads (27%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs747274448; called by muse, mutect2, varscan2
- NCAPD3 | c.4307G>A p.R1436Q | Missense Mutation (SNP) | VAF 76/352 reads (22%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs890752834, COSV54457570; called by muse, mutect2, varscan2
- NEURL3 | c.349G>A p.A117T | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.053); catalogued as rs549194101; called by muse, mutect2, varscan2
- NFE2L1 | c.485dup p.V163Sfs*14 | Frame Shift Ins (INS) | VAF 14/87 reads (16%) | catalogued as rs773403681; called by mutect2, varscan2
- NIPA2 | c.101del p.G34Afs*11 | Frame Shift Del (DEL) | VAF 36/125 reads (29%) | catalogued as rs111948120; called by mutect2, pindel, varscan2
- NLGN2 | c.149G>A p.R50Q | Missense Mutation (SNP) | VAF 50/250 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as rs1306151640; called by muse, mutect2, varscan2
- NLGN4X | c.1172C>T p.T391M | Missense Mutation (SNP) | VAF 38/397 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.961); catalogued as rs761689770; called by muse, mutect2, varscan2
- NLRP12 | c.466C>T p.R156W | Missense Mutation (SNP) | VAF 121/494 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs145803984, COSV60749290, COSV60756422; called by muse, mutect2, varscan2
- NOP58 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 37/148 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs750188563, COSV51895393, COSV51895891; called by muse, mutect2, varscan2
- NOS2 | c.1864G>A p.A622T | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.889); catalogued as rs748601061, COSV104402635; called by muse, mutect2, varscan2
- NPTXR | c.824A>G p.Q275R | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.714); catalogued as rs779666889; called by muse, mutect2, varscan2
- NPY1R | c.930G>A p.M310I | Missense Mutation (SNP) | VAF 25/250 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as rs1337239706; called by muse, mutect2
- NRXN3 | c.530G>A p.R177H (on ENST00000557594 / NM_001272020.2; = p.R809H on NM_004796.6) | Missense Mutation (SNP) | VAF 79/232 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.408); catalogued as COSV55333269; called by muse, mutect2, varscan2
- NSD1 | c.5917G>T p.G1973C | Missense Mutation (SNP) | VAF 28/254 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61781621; called by muse, varscan2
- NTAN1 | c.831del p.K277Nfs*83 | Frame Shift Del (DEL) | VAF 30/189 reads (16%) | catalogued as COSV55073962; called by mutect2, pindel, varscan2
- NXPE1 | c.1412C>G p.T471S (on ENST00000424269; = p.T329S on NM_152315.5) | Missense Mutation (SNP) | VAF 54/244 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs776200189; called by muse, mutect2, varscan2
- NXPH1 | c.46G>A p.V16I | Missense Mutation (SNP) | VAF 81/349 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV68314039; called by muse, mutect2, varscan2
- OBSCN | c.6127C>T p.R2043C | Missense Mutation (SNP) | VAF 24/330 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs1311739481; called by muse, mutect2
- ODAPH | c.225del p.P76Hfs*87 | Frame Shift Del (DEL) | VAF 160/637 reads (25%) | catalogued as COSV61141950; called by mutect2, varscan2
- OPRK1 | c.971G>A p.S324N | Missense Mutation (SNP) | VAF 101/370 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.969); catalogued as rs1274571614, COSV99654253; called by muse, mutect2, varscan2
- OR1M1 | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 120/431 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.071); catalogued as rs765053649, COSV70036933; called by muse, mutect2, varscan2
- OR5H2 | c.698del p.K233Rfs*7 | Frame Shift Del (DEL) | VAF 26/150 reads (17%) | catalogued as COSV62349977; called by mutect2, pindel, varscan2
- OR5L1 | c.482G>A p.C161Y | Missense Mutation (SNP) | VAF 15/275 reads (5%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.953); catalogued as COSV100449865; called by muse, mutect2
- PAPPA2 | c.3169C>T p.R1057C | Missense Mutation (SNP) | VAF 46/135 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs376569973, COSV62814669; called by muse, mutect2, varscan2
- PAQR7 | c.310G>A p.A104T | Missense Mutation (SNP) | VAF 70/228 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.406); catalogued as rs142505796; called by muse, mutect2, varscan2
- PARD6B | c.701T>C p.M234T | Missense Mutation (SNP) | VAF 25/293 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs769007120, COSV65405057; called by muse, mutect2
- PCDHGA4 | c.1123G>A p.A375T | Missense Mutation (SNP) | VAF 25/317 reads (8%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.043); catalogued as rs551700676; called by muse, mutect2
- PCDHGB2 | c.1778C>T p.A593V | Missense Mutation (SNP) | VAF 22/352 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1238388827, COSV53946351; called by muse, mutect2
- PCSK1 | c.1660A>G p.M554V | Missense Mutation (SNP) | VAF 32/241 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as rs1163493723, COSV60734861; called by muse, mutect2, varscan2
- PCSK1N | c.424C>T p.R142C | Missense Mutation (SNP) | VAF 19/127 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.927); catalogued as COSV54433028; called by muse, mutect2, varscan2
- PDCD6 | c.307G>A p.D103N | Missense Mutation (SNP) | VAF 34/475 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1004444042; called by muse, mutect2
- PDE8B | c.164del p.P55Rfs*10 | Frame Shift Del (DEL) | VAF 25/236 reads (11%) | catalogued as COSV53744232; called by mutect2, pindel
- PELP1 | c.2392del p.L798Cfs*14 | Frame Shift Del (DEL) | VAF 11/133 reads (8%) | catalogued as rs752653446, COSV99342923; called by mutect2, pindel
- PGLYRP2 | c.956G>A p.R319Q | Missense Mutation (SNP) | VAF 47/177 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs535549580, COSV52993092; called by muse, mutect2, varscan2
- PHOX2A | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); catalogued as rs1479879253, COSV53359303; called by muse, mutect2, varscan2
- PI4KB | c.196G>A p.V66M (on ENST00000368873 / NM_001369623.1; = p.V78M on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/180 reads (19%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as rs867711084, COSV99649298; called by muse, mutect2, varscan2
- PIK3CA | c.317G>A p.G106D | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55874291, COSV55888676, COSV55926774; called by muse, mutect2, varscan2
- PKD1 | c.5065G>A p.E1689K | Missense Mutation (SNP) | VAF 68/282 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.047); catalogued as rs534630703, COSV51917382; called by muse, mutect2, varscan2
- PLA2G4F | c.2018G>A p.R673Q | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.042); catalogued as rs748772682, COSV99300652; called by muse, mutect2, varscan2
- PLCG2 | c.1745G>A p.R582Q | Missense Mutation (SNP) | VAF 42/160 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as rs200325678, COSV63868709; called by muse, mutect2, varscan2
- PLEC | c.7202G>A p.R2401H (on ENST00000322810 / NM_201380.4; = p.R2291H on NM_000445.5) | Missense Mutation (SNP) | VAF 217/846 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.379); catalogued as rs201661279, COSV100519168; ClinVar: uncertain significance; called by muse, varscan2
- PLEKHH2 | c.4040del p.P1347Hfs*13 | Frame Shift Del (DEL) | VAF 44/174 reads (25%) | catalogued as COSV99175125; called by mutect2, pindel, varscan2
- PLEKHH3 | c.574del p.V192Wfs*6 | Frame Shift Del (DEL) | VAF 13/111 reads (12%) | catalogued as rs778393033; called by mutect2, pindel, varscan2
- PLXNA3 | c.49del p.A17Pfs*12 | Frame Shift Del (DEL) | VAF 40/162 reads (25%) | catalogued as rs782247826; called by mutect2, varscan2
- POLE | c.6379C>T p.R2127* | Nonsense Mutation (SNP) | VAF 14/410 reads (3%) | catalogued as rs1057517583, COSV57681995; ClinVar: uncertain significance; called by muse, mutect2
- POLRMT | c.2623G>A p.A875T | Missense Mutation (SNP) | VAF 33/310 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750855835, COSV52117472; called by muse, mutect2
- POMT1 | c.1585C>T p.H529Y | Missense Mutation (SNP) | VAF 84/568 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.159); catalogued as rs148790434; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.2003C>T p.A668V | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs142011996; called by muse, mutect2, varscan2
- PPFIA4 | c.3347G>A p.R1116H (on ENST00000447715; = p.R1117H on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs1414639385; called by muse, mutect2, varscan2
- PPIG | c.151G>A p.G51R | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1434858664, COSV53641955; called by muse, mutect2, varscan2
- PPM1D | c.1349del p.L450* | Frame Shift Del (DEL) | VAF 49/179 reads (27%) | catalogued as rs758630849; called by mutect2, pindel, varscan2
- PPP1R37 | c.1296G>A p.A432= | Splice Region (SNP) | VAF 6/80 reads (8%) | catalogued as rs1280330101; called by muse, mutect2
- PPP2R2C | c.1111C>T p.R371W | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as rs1340045766; called by muse, mutect2, varscan2
- PPP4R3C | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 13/267 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs1293217889; called by muse, mutect2
- PRDM1 | c.1556C>T p.A519V | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.57); catalogued as rs376600972; called by muse, mutect2, varscan2
- PRKDC | c.8179C>T p.R2727* | Nonsense Mutation (SNP) | VAF 6/84 reads (7%) | catalogued as COSV58044373; called by muse, mutect2
- PRPSAP1 | c.674C>T p.A225V | Missense Mutation (SNP) | VAF 60/200 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); catalogued as rs867761502; called by muse, mutect2, varscan2
- PRR15L | c.116C>A p.P39H | Missense Mutation (SNP) | VAF 12/149 reads (8%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs1383738082, COSV56023884; called by muse, mutect2
- PRRC1 | c.1262G>A p.R421H | Missense Mutation (SNP) | VAF 113/503 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs141931246; called by muse, mutect2, varscan2
- PTGES3L-AARSD1 | c.1429G>A p.D477N (on ENST00000421990 / NM_001136042.2; = p.D459N on NM_025267.3) | Missense Mutation (SNP) | VAF 77/260 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.913); catalogued as rs768805369; called by muse, mutect2, varscan2
- PTPN6 | c.1660C>T p.R554C | Missense Mutation (SNP) | VAF 94/522 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.483); catalogued as rs782599498, COSV100016826, COSV100016895; called by muse, mutect2, varscan2
- PTPRB | c.4106C>T p.T1369M | Missense Mutation (SNP) | VAF 49/174 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767350132, COSV54238573, COSV54241567; called by muse, mutect2, varscan2
- PTPRS | c.3191C>T p.T1064I | Missense Mutation (SNP) | VAF 14/272 reads (5%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs1195525448; called by muse, mutect2
- PTPRU | c.2348+1G>A p.X783_splice | Splice Site (SNP) | VAF 50/335 reads (15%) | catalogued as rs760447683, COSV60521097, COSV99057688; called by muse, mutect2, varscan2
- PXDNL | c.2183G>A p.R728H | Missense Mutation (SNP) | VAF 28/251 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100681371; called by muse, mutect2, varscan2
- QSER1 | c.5090del p.N1697Mfs*4 (on ENST00000399302; = p.N1826Mfs*4 on NM_001076786.3) | Frame Shift Del (DEL) | VAF 8/38 reads (21%) | catalogued as rs754588466; called by mutect2, varscan2
- RAB11FIP1 | c.3533C>A p.P1178H (on ENST00000330843 / NM_001002814.3; = p.P544H on NM_025151.5) | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99769570; called by muse, mutect2, varscan2
- RABGAP1 | c.745C>T p.R249W | Missense Mutation (SNP) | VAF 41/209 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs897382844, COSV58059964; called by muse, mutect2, varscan2
- RAI1 | c.1979G>A p.R660Q | Missense Mutation (SNP) | VAF 42/562 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs377537260; ClinVar: likely benign; called by muse, mutect2
- RASA4 | c.34G>A p.V12M | Missense Mutation (SNP) | VAF 27/350 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); catalogued as rs758432172; called by muse, mutect2
- RAVER1 | c.1097del p.P366Qfs*169 (on ENST00000615032; = p.P366Qfs*141 on NM_133452.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 7/34 reads (21%) | catalogued as rs768618392, COSV53348646; called by mutect2, pindel, varscan2
- RBM10 | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 118/438 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs139829599, COSV61311081; called by muse, varscan2
- RDH11 | c.911G>A p.R304Q | Missense Mutation (SNP) | VAF 45/204 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.769); catalogued as rs766902543, COSV99373756; called by muse, mutect2, varscan2
- RFXAP | c.703del p.R235Dfs*5 | Frame Shift Del (DEL) | VAF 20/75 reads (27%) | catalogued as rs1566320519; called by mutect2, pindel, varscan2
- RGPD3 | c.3500G>A p.C1167Y | Missense Mutation (SNP) | VAF 78/738 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs968504501, COSV104393550; called by muse, mutect2, varscan2
- RGPD3 | c.1790G>A p.R597Q | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.129); catalogued as rs1369426630; called by mutect2, varscan2
- RGS12 | c.3534del p.K1178Nfs*32 | Frame Shift Del (DEL) | VAF 18/42 reads (43%) | catalogued as rs753542639, COSV58750063; called by mutect2, varscan2
- RHOBTB1 | c.1894C>T p.R632C | Missense Mutation (SNP) | VAF 64/276 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); catalogued as rs746517061, COSV61958099; called by muse, mutect2, varscan2
- RP1L1 | c.6173C>T p.P2058L | Missense Mutation (SNP) | VAF 81/328 reads (25%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs374789384; called by muse, mutect2, varscan2
- RPL15 | c.287G>A p.R96Q | Missense Mutation (SNP) | VAF 43/187 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.274); catalogued as rs748334045, COSV57140624; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 26/214 reads (12%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPTOR | c.1228G>A p.A410T | Missense Mutation (SNP) | VAF 47/169 reads (28%) | SIFT tolerated (0.61); PolyPhen benign (0.01); catalogued as rs1567946390; called by muse, mutect2, varscan2
- RRP36 | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 56/186 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.32); catalogued as rs779762073; called by muse, mutect2, varscan2
- RYR2 | c.2543G>A p.R848H | Missense Mutation (SNP) | VAF 84/299 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs1247047478; called by muse, mutect2, varscan2
- RYR2 | c.5017G>A p.A1673T | Missense Mutation (SNP) | VAF 19/288 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63682760; called by muse, mutect2
- RYR3 | c.1006C>T p.R336* | Nonsense Mutation (SNP) | VAF 47/175 reads (27%) | catalogued as rs370675640; called by muse, mutect2, varscan2
- SAPCD1 | c.223C>T p.R75* | Nonsense Mutation (SNP) | VAF 38/146 reads (26%) | catalogued as rs765030533; called by muse, mutect2
- SCCPDH | c.1177C>T p.P393S | Missense Mutation (SNP) | VAF 29/208 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1217639173; called by muse, mutect2, varscan2
- SCN10A | c.4280del p.K1427Sfs*2 | Frame Shift Del (DEL) | VAF 12/38 reads (32%) | catalogued as rs750400627; called by mutect2, varscan2
- SCN3A | c.2052_2054del p.R685del | In Frame Del (DEL) | VAF 88/381 reads (23%) | catalogued as rs766645534; called by mutect2, pindel, varscan2
- SDF4 | c.395T>C p.M132T | Missense Mutation (SNP) | VAF 20/286 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs1435900442; called by muse, mutect2
- SEC16A | c.1689del p.F563Lfs*9 | Frame Shift Del (DEL) | VAF 86/384 reads (22%) | catalogued as COSV99255876; called by mutect2, pindel, varscan2
- SENP2 | c.274G>A p.V92M | Missense Mutation (SNP) | VAF 9/175 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.191); catalogued as rs1249439228; called by muse, mutect2
- SEPTIN14 | c.1289G>A p.R430H | Missense Mutation (SNP) | VAF 22/317 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.046); catalogued as rs777286266, COSV66428692; called by muse, mutect2
- SEPTIN2 | c.290T>C p.L97P | Missense Mutation (SNP) | VAF 64/281 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1418689196; called by muse, mutect2, varscan2
- SERPING1 | c.265C>T p.Q89* | Nonsense Mutation (SNP) | VAF 36/522 reads (7%) | catalogued as CM083103; called by muse, mutect2
- SEZ6L2 | c.2275G>A p.D759N (on ENST00000308713 / NM_001114099.3; = p.D689N on NM_012410.4) | Missense Mutation (SNP) | VAF 73/256 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs369862327; called by muse, mutect2, varscan2
- SH3BP4 | c.1630A>G p.N544D | Missense Mutation (SNP) | VAF 69/346 reads (20%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.989); catalogued as COSV100749365; called by muse, mutect2, varscan2
- SH3D21 | c.1811C>T p.A604V (on ENST00000453908 / NM_001162530.2; = p.A493V on NM_024676.5) | Missense Mutation (SNP) | VAF 44/142 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs774669190; called by muse, mutect2, varscan2
- SHANK3 | c.3715G>A p.A1239T | Missense Mutation (SNP) | VAF 14/242 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as rs1160186820; called by muse, mutect2
- SHMT2 | c.1273C>T p.R425W | Missense Mutation (SNP) | VAF 45/177 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754743336; called by muse, mutect2, varscan2
- SIRT6 | c.80del p.P27Rfs*133 | Frame Shift Del (DEL) | VAF 15/89 reads (17%) | catalogued as rs766524945, COSV59446625; called by mutect2, pindel, varscan2
- SKI | c.62T>C p.L21P | Missense Mutation (SNP) | VAF 91/353 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as CM129807; called by muse, mutect2, varscan2
- SKIV2L | c.380C>T p.S127L | Missense Mutation (SNP) | VAF 74/181 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.388); catalogued as rs140350010; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC13A4 | c.43C>G p.L15V | Missense Mutation (SNP) | VAF 32/165 reads (19%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.997); catalogued as rs778055510, COSV100647334; called by muse, mutect2, varscan2
- SLC16A11 | c.82del p.Q28Sfs*21 (on ENST00000308009; = p.Q4Sfs*21 on NM_153357.3) | Frame Shift Del (DEL) | VAF 31/108 reads (29%) | catalogued as rs139324407; called by mutect2, pindel, varscan2
- SLC25A24 | c.570del p.K190Nfs*29 | Frame Shift Del (DEL) | VAF 44/203 reads (22%) | catalogued as rs763273320; called by mutect2, varscan2
- SLC35A4 | c.605C>T p.S202L | Missense Mutation (SNP) | VAF 60/271 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as rs773001559; called by muse, mutect2, varscan2
- SLC35A5 | c.898del p.Y300Mfs*8 | Frame Shift Del (DEL) | VAF 19/215 reads (9%) | catalogued as rs1363537717; called by mutect2, pindel
- SLC35B3 | c.967G>A p.A323T | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100217097; called by muse, mutect2, varscan2
- SLC35G2 | c.192del p.R66Efs*18 | Frame Shift Del (DEL) | VAF 36/121 reads (30%) | catalogued as rs750825208; called by mutect2, varscan2
- SLC4A10 | c.574G>C p.A192P | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV55793337; called by muse, mutect2, varscan2
- SLC5A12 | c.789C>A p.C263* | Nonsense Mutation (SNP) | VAF 14/186 reads (8%) | catalogued as COSV54825411; called by muse, mutect2
- SLC5A9 | c.412C>T p.P138S | Missense Mutation (SNP) | VAF 50/245 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52581963; called by muse, mutect2, varscan2
- SLC6A8 | c.1693G>A p.A565T | Missense Mutation (SNP) | VAF 166/568 reads (29%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.6); catalogued as rs1557045723, COSV53471836; called by muse, mutect2, varscan2
- SLC7A14 | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 47/293 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs1329066774, COSV51577945; called by muse, mutect2, varscan2
- SLITRK2 | c.1060G>A p.G354S | Missense Mutation (SNP) | VAF 55/235 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1556944372; called by muse, mutect2, varscan2
- SMARCA1 | c.380G>A p.R127H | Missense Mutation (SNP) | VAF 21/216 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as rs1178782625; called by muse, mutect2
- SMCO4 | c.158C>T p.T53M | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as rs750629862; called by muse, mutect2, varscan2
- SNX12 | c.466G>A p.V156I | Missense Mutation (SNP) | VAF 26/240 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs1048883139, COSV52146027; called by muse, varscan2
- SNX13 | c.2380C>T p.R794* | Nonsense Mutation (SNP) | VAF 12/52 reads (23%) | catalogued as rs747423629, COSV101296789, COSV68068850; called by muse, mutect2, varscan2
- SORCS3 | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.215); catalogued as rs1388743660, COSV63802949; called by muse, mutect2
- SP6 | c.928G>A p.G310S | Missense Mutation (SNP) | VAF 121/368 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752843805, COSV100646929; called by muse, mutect2, varscan2
- SPATA6L | c.449G>A p.R150Q (on ENST00000461761 / NM_001353484.2; = p.R92Q on NM_001039395.4 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs769063008; called by muse, mutect2, varscan2
- SPEN | c.7721C>T p.P2574L | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs201347979; called by muse, mutect2, varscan2
- SPTBN4 | c.6800C>T p.P2267L | Missense Mutation (SNP) | VAF 30/305 reads (10%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as rs767240147; called by muse, mutect2
- SRCAP | c.9070G>A p.V3024I | Missense Mutation (SNP) | VAF 57/212 reads (27%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.039); catalogued as rs755074363; called by muse, mutect2, varscan2
- SRL | c.592C>T p.R198C | Missense Mutation (SNP) | VAF 70/213 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1054627779; called by muse, mutect2, varscan2
- SRSF1 | c.158del p.G53Dfs*85 | Frame Shift Del (DEL) | VAF 33/126 reads (26%) | catalogued as COSV51964296, COSV51965809; called by mutect2, pindel, varscan2
- STAC | c.187C>T p.R63* | Nonsense Mutation (SNP) | VAF 18/414 reads (4%) | catalogued as rs1048947611; called by muse, mutect2
- STRA8 | c.685G>A p.V229M (on ENST00000275764; = p.V207M on NM_182489.2) | Missense Mutation (SNP) | VAF 71/236 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.204); catalogued as rs1430655522, COSV51960722; called by muse, mutect2, varscan2
- SUSD1 | c.1936G>A p.A646T | Missense Mutation (SNP) | VAF 52/402 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs765774346, COSV62585585; called by muse, mutect2, varscan2
- SVIL | c.5586del p.M1863Wfs*44 (on ENST00000355867 / NM_021738.3; = p.M1437Wfs*44 on NM_003174.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 16/222 reads (7%) | catalogued as rs770033147; called by mutect2, pindel
- TACC2 | c.2347del p.Q783Rfs*32 | Frame Shift Del (DEL) | VAF 64/257 reads (25%) | catalogued as rs750901207; called by mutect2, pindel, varscan2
- TAGLN | c.206T>C p.L69P | Missense Mutation (SNP) | VAF 11/195 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99639014; called by muse, mutect2
- TAS1R3 | c.1812dup p.P605Afs*238 | Frame Shift Ins (INS) | VAF 30/140 reads (21%) | catalogued as rs777573279; called by mutect2, varscan2
- TAX1BP1 | c.1147G>A p.V383I | Missense Mutation (SNP) | VAF 150/545 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.455); catalogued as rs979870030, COSV55290560, COSV55291444; called by muse, mutect2, varscan2
- TBC1D22B | c.530del p.P177Qfs*2 | Frame Shift Del (DEL) | VAF 30/194 reads (15%) | catalogued as rs757209781; called by mutect2, pindel, varscan2
- TBC1D23 | c.1947del p.K649Nfs*18 (on ENST00000394144 / NM_001199198.3; = p.K634Nfs*18 on NM_018309.5) | Frame Shift Del (DEL) | VAF 22/65 reads (34%) | catalogued as rs747637295, COSV61367528; called by mutect2, varscan2
- TBC1D26 | c.178G>A p.V60I | Missense Mutation (SNP) | VAF 36/188 reads (19%) | SIFT tolerated (0.46); PolyPhen benign (0.009); catalogued as rs543911529; called by muse, mutect2, varscan2
- TCERG1L | c.872G>A p.R291Q | Missense Mutation (SNP) | VAF 39/143 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.033); catalogued as rs1478202224; called by muse, mutect2, varscan2
- TCHHL1 | c.1223G>A p.R408H | Missense Mutation (SNP) | VAF 75/218 reads (34%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs754236943, COSV64286786; called by muse, mutect2, varscan2
- TEAD2 | c.513del p.W172Gfs*6 | Frame Shift Del (DEL) | VAF 26/151 reads (17%) | catalogued as rs763523079; called by mutect2, pindel, varscan2
- TEK | c.224C>T p.T75I | Missense Mutation (SNP) | VAF 26/392 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.011); catalogued as rs761822823; called by muse, mutect2
- TENM1 | c.3190G>T p.G1064W | Missense Mutation (SNP) | VAF 66/266 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100948987; called by muse, mutect2, varscan2
- TEX2 | c.823C>T p.R275C | Missense Mutation (SNP) | VAF 82/336 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs782097534, COSV51978559; called by muse, mutect2, varscan2
- THEMIS2 | c.10G>A p.V4M | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.022); catalogued as COSV61078544; called by muse, mutect2, varscan2
- TICAM1 | c.1925del p.P642Hfs*50 | Frame Shift Del (DEL) | VAF 9/30 reads (30%) | catalogued as COSV50235787; called by mutect2, pindel, varscan2
- TIMD4 | c.280G>A p.D94N | Missense Mutation (SNP) | VAF 74/345 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.044); catalogued as COSV50853965, COSV50855746; called by muse, mutect2, varscan2
- TLN1 | c.7552G>A p.A2518T | Missense Mutation (SNP) | VAF 39/235 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1307631134; called by muse, mutect2, varscan2
- TMC6 | c.697G>A p.A233T | Missense Mutation (SNP) | VAF 88/322 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.069); catalogued as rs758146730; called by muse, varscan2
- TMEM132D | c.718G>A p.V240I | Missense Mutation (SNP) | VAF 93/373 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs1313552966, COSV70593014; called by muse, mutect2, varscan2
- TMEM200A | c.261del p.E88Nfs*38 | Frame Shift Del (DEL) | VAF 30/103 reads (29%) | catalogued as COSV51651372; called by mutect2, pindel, varscan2
- TMEM39A | c.633_635del p.L212del | In Frame Del (DEL) | VAF 31/105 reads (30%) | catalogued as rs780208580; called by pindel, varscan2
- TMEM40 | c.658del p.L220Sfs*7 | Frame Shift Del (DEL) | VAF 44/197 reads (22%) | catalogued as rs774951652, COSV53147262; called by mutect2, pindel, varscan2
- TNC | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs150265065; called by muse, mutect2, varscan2
- TNXB | c.5521G>A p.G1841S (on ENST00000647633; = p.G1594S on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/370 reads (5%) | SIFT tolerated (0.98); PolyPhen possibly damaging (0.55); catalogued as COSV64487145; called by muse, mutect2
- TRABD2A | c.746C>T p.T249M | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs957212882; called by muse, mutect2, varscan2
- TRAF3IP3 | c.73C>T p.R25C | Missense Mutation (SNP) | VAF 20/264 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs759256006, COSV50550568, COSV99160299; called by muse, mutect2
- TRIM46 | c.1634G>A p.R545Q | Missense Mutation (SNP) | VAF 65/214 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as rs983090032, COSV58114671; called by muse, mutect2, varscan2
- TRPM6 | c.2065C>T p.R689C | Missense Mutation (SNP) | VAF 70/256 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.586); catalogued as rs768922534, COSV62513869; called by muse, mutect2, varscan2
- TSHZ3 | c.580G>A p.V194M | Missense Mutation (SNP) | VAF 40/141 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53669709; called by muse, mutect2, varscan2
- TTC12 | c.1831A>G p.M611V | Missense Mutation (SNP) | VAF 68/243 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1241600720, COSV59099795; called by muse, mutect2, varscan2
- TULP4 | c.1207del p.R403Afs*24 | Frame Shift Del (DEL) | VAF 52/216 reads (24%) | catalogued as rs746002490; called by mutect2, pindel, varscan2
- UBC | c.1300C>T p.R434C | Missense Mutation (SNP) | VAF 64/516 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as rs745364694; called by muse, varscan2
- VAV3 | c.961C>T p.R321* | Nonsense Mutation (SNP) | VAF 22/107 reads (21%) | catalogued as rs1252178608; called by muse, mutect2, varscan2
- VIPR2 | c.173_175del p.N58del | In Frame Del (DEL) | VAF 44/198 reads (22%) | catalogued as rs780279954; called by pindel, varscan2
- VPS13D | c.1036G>A p.A346T | Missense Mutation (SNP) | VAF 30/226 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100691962; called by muse, mutect2, varscan2
- WDFY3 | c.4736G>A p.S1579N | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV55695798; called by muse, mutect2, varscan2
- WDR3 | c.2786_2788del p.K929del | In Frame Del (DEL) | VAF 34/118 reads (29%) | catalogued as rs780836502; called by pindel, varscan2
- WDTC1 | c.868del p.E290Nfs*8 | Frame Shift Del (DEL) | VAF 34/142 reads (24%) | catalogued as rs747972901, COSV60089251; called by mutect2, varscan2
- XBP1 | c.695G>A p.R232K | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as rs1379560430; called by muse, mutect2, varscan2
- XKR8 | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 35/141 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0.038); catalogued as rs575511459; called by muse, mutect2, varscan2
- ZAN | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 65/596 reads (11%) | SIFT tolerated (0.6); PolyPhen benign (0.245); catalogued as rs769810485, COSV61807537, COSV61816885; called by muse, mutect2, varscan2
- ZCCHC4 | c.960del p.F320Lfs*19 | Frame Shift Del (DEL) | VAF 17/84 reads (20%) | catalogued as rs760215323; called by mutect2, varscan2
- ZDHHC8 | c.1374del p.T459Rfs*177 | Frame Shift Del (DEL) | VAF 19/78 reads (24%) | catalogued as rs781677398, COSV57709922; called by mutect2, pindel, varscan2
- ZFHX3 | c.314dup p.P106Afs*13 | Frame Shift Ins (INS) | VAF 8/46 reads (17%) | catalogued as rs769936196; called by pindel, varscan2
- ZFP36 | c.736del p.L246Wfs*126 (on ENST00000594442; = p.L240Wfs*126 on NM_003407.5) | Frame Shift Del (DEL) | VAF 28/107 reads (26%) | catalogued as rs1568383502; called by mutect2, pindel, varscan2
- ZMYM2 | c.3131del p.K1044Rfs*33 | Frame Shift Del (DEL) | VAF 28/70 reads (40%) | catalogued as rs753611080; called by mutect2, varscan2
- ZNF106 | c.1444del p.S482Pfs*33 | Frame Shift Del (DEL) | VAF 46/202 reads (23%) | catalogued as rs1198467282, COSV55516091; called by mutect2, varscan2
- ZNF189 | c.956_958del p.G319del | In Frame Del (DEL) | VAF 26/149 reads (17%) | catalogued as rs755642941; called by pindel, varscan2
- ZNF419 | c.332C>T p.P111L | Missense Mutation (SNP) | VAF 40/145 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.122); catalogued as COSV55657604; called by muse, mutect2, varscan2
- ZNF429 | c.1988G>A p.R663Q | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.061); catalogued as rs368726828; called by muse, mutect2
- ZNF672 | c.718G>A p.A240T | Missense Mutation (SNP) | VAF 46/146 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.123); catalogued as rs865914791, COSV60637349; called by muse, mutect2, varscan2
- ZNF672 | c.935C>T p.A312V | Missense Mutation (SNP) | VAF 35/173 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1276324050; called by muse, mutect2, varscan2
- ZNF777 | c.2323G>A p.E775K | Missense Mutation (SNP) | VAF 45/161 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99925167; called by muse, mutect2, varscan2
- ZNF831 | c.1067C>T p.P356L | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); catalogued as rs1383621842, COSV100925905; called by muse, mutect2, varscan2
- ZSCAN20 | c.2767C>T p.R923C | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773355618; called by muse, mutect2, varscan2
- ZSWIM8 | c.5005C>T p.R1669C (on ENST00000605216 / NM_001242487.2; = p.R1674C on NM_015037.3) | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as COSV100014431; called by muse, mutect2
- ABCA2 | c.746del p.G249Afs*216 (on ENST00000614293; = p.G219Afs*216 on NM_001606.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 66/225 reads (29%) | called by mutect2, pindel, varscan2
- ABCB1 | c.2565G>A p.W855* | Nonsense Mutation (SNP) | VAF 35/162 reads (22%) | called by muse, mutect2, varscan2
- ABCB7 | c.959T>C p.I320T (on ENST00000373394 / NM_001271696.3; = p.I321T on NM_004299.6) | Missense Mutation (SNP) | VAF 9/198 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.18); called by muse, mutect2
- AC004997.1 | c.751+1del p.X251_splice | Splice Site (DEL) | VAF 39/157 reads (25%) | called by mutect2, pindel, varscan2
- ACKR2 | c.107G>A p.C36Y | Missense Mutation (SNP) | VAF 24/236 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.38); called by muse, mutect2
- ADAMTS13 | c.3622C>A p.P1208T | Missense Mutation (SNP) | VAF 26/543 reads (5%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, mutect2
- ADAMTS17 | c.2746T>C p.C916R | Missense Mutation (SNP) | VAF 27/320 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ADAMTS4 | c.704G>A p.G235D | Missense Mutation (SNP) | VAF 65/236 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- ADCY5 | c.1306C>T p.L436F | Missense Mutation (SNP) | VAF 19/230 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); called by muse, mutect2
- ADGRA2 | c.3010G>A p.G1004R | Missense Mutation (SNP) | VAF 15/146 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.078); called by muse, mutect2
- ADRA2C | c.548C>A p.S183Y | Missense Mutation (SNP) | VAF 31/339 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- AFDN | c.5366T>C p.L1789S (on ENST00000447894 / NM_001366320.1; = p.L1708S on NM_001207008.1) | Missense Mutation (SNP) | VAF 20/210 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AFP | c.19A>T p.I7F | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- AGAP2 | c.2524T>C p.S842P (on ENST00000547588 / NM_001122772.2; = p.S506P on NM_014770.4) | Missense Mutation (SNP) | VAF 9/185 reads (5%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.947); called by muse, mutect2
- AHCTF1 | c.3320T>A p.I1107K (on ENST00000366508; = p.I1081K on NM_015446.5) | Missense Mutation (SNP) | VAF 8/127 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- AHCY | c.376A>G p.N126D | Missense Mutation (SNP) | VAF 25/412 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2
- AHSG | c.1014A>T p.K338N | Missense Mutation (SNP) | VAF 35/256 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- ALDH1A2 | c.710A>T p.N237I | Missense Mutation (SNP) | VAF 44/405 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ALKAL2 | c.74del p.G25Afs*67 | Frame Shift Del (DEL) | VAF 14/123 reads (11%) | called by mutect2, pindel
- ALS2CL | c.2223G>T p.Q741H | Missense Mutation (SNP) | VAF 14/219 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2
- AMN | c.185_187del p.E62del | In Frame Del (DEL) | VAF 153/532 reads (29%) | called by pindel, varscan2
- AMPD2 | c.737del p.P246Lfs*63 | Frame Shift Del (DEL) | VAF 38/168 reads (23%) | called by mutect2, varscan2
- ANGPT1 | c.1410del p.K470Nfs*2 | Frame Shift Del (DEL) | VAF 37/209 reads (18%) | called by mutect2, pindel, varscan2
- ANKLE2 | c.140C>A p.T47N | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ANKRD26 | c.236T>C p.M79T | Missense Mutation (SNP) | VAF 46/401 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AP1B1 | c.209A>G p.Y70C | Missense Mutation (SNP) | VAF 17/190 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- APBA2 | c.1310G>T p.R437M | Missense Mutation (SNP) | VAF 40/504 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- APOB | c.3565del p.M1189* | Frame Shift Del (DEL) | VAF 32/324 reads (10%) | called by mutect2, pindel
- ARF1 | c.472A>T p.T158S | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.047); called by muse, mutect2
- ARHGAP4 | c.416T>C p.V139A | Missense Mutation (SNP) | VAF 75/281 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- ARNT2 | c.284C>T p.A95V | Missense Mutation (SNP) | VAF 29/412 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2
- ASF1B | c.497A>G p.Q166R | Missense Mutation (SNP) | VAF 43/175 reads (25%) | SIFT tolerated (0.46); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- ATP2B3 | c.1307C>T p.A436V | Missense Mutation (SNP) | VAF 24/227 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ATP6V1E1 | c.436-2A>G p.X146_splice | Splice Site (SNP) | VAF 18/147 reads (12%) | called by muse, mutect2, varscan2
- ATP8B2 | c.1831C>A p.L611I (on ENST00000672630; = p.L578I on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/259 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ATXN1 | c.485C>T p.A162V | Missense Mutation (SNP) | VAF 36/263 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ATXN2 | c.1787del p.P596Rfs*52 (on ENST00000550104; = p.P436Rfs*52 on NM_002973.4) | Frame Shift Del (DEL) | VAF 12/73 reads (16%) | called by mutect2, pindel, varscan2
- AUP1 | c.19C>T p.P7S | Missense Mutation (SNP) | VAF 39/145 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- AVL9 | c.515C>A p.S172Y | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.746); called by muse, mutect2, varscan2
- BICRA | c.1679C>T p.S560L | Missense Mutation (SNP) | VAF 7/119 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.116); called by muse, mutect2
- BIVM-ERCC5 | c.1334C>T p.A445V | Missense Mutation (SNP) | VAF 50/454 reads (11%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BRF1 | c.876del p.S293Rfs*11 | Frame Shift Del (DEL) | VAF 20/226 reads (9%) | called by mutect2, pindel
- BYSL | c.55del p.L19Wfs*36 | Frame Shift Del (DEL) | VAF 27/107 reads (25%) | called by mutect2, pindel, varscan2
- C12orf54 | c.52A>G p.K18E | Missense Mutation (SNP) | VAF 32/178 reads (18%) | SIFT tolerated (0.64); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C16orf96 | c.1043C>T p.P348L | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- CABP2 | c.32G>T p.R11L | Missense Mutation (SNP) | VAF 47/133 reads (35%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CACNA1H | c.1861del p.V621Wfs*29 | Frame Shift Del (DEL) | VAF 88/338 reads (26%) | called by mutect2, pindel, varscan2
- CACNA1H | c.4360G>T p.G1454W | Missense Mutation (SNP) | VAF 57/164 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CAMK1G | c.1147G>A p.A383T | Missense Mutation (SNP) | VAF 82/329 reads (25%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- CARD9 | c.1357+7T>C | Splice Region (SNP) | VAF 17/229 reads (7%) | called by muse, mutect2
- CBLC | c.1418del p.P473Rfs*? | Frame Shift Del (DEL) | VAF 9/98 reads (9%) | called by mutect2, pindel
- CBX4 | c.70-2A>G p.X24_splice | Splice Site (SNP) | VAF 18/99 reads (18%) | called by mutect2, varscan2
- CCDC160 | c.51del p.F17Lfs*7 | Frame Shift Del (DEL) | VAF 9/59 reads (15%) | called by mutect2, pindel
- CCDC180 | c.2924T>C p.L975P | Missense Mutation (SNP) | VAF 47/233 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC183 | c.313A>T p.N105Y | Missense Mutation (SNP) | VAF 45/207 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- CCDC27 | c.1681_1683del p.K561del | In Frame Del (DEL) | VAF 36/162 reads (22%) | called by pindel, varscan2
- CCDC39 | c.1528-5dup | Splice Region (INS) | VAF 9/37 reads (24%) | called by mutect2, pindel
- CCDC80 | c.1376G>A p.G459D | Missense Mutation (SNP) | VAF 26/298 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2
- CCDC86 | c.319C>T p.P107S | Missense Mutation (SNP) | VAF 90/335 reads (27%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- CDC42BPA | c.3277A>G p.K1093E (on ENST00000334218 / NM_001366019.2; = p.K1080E on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDC42BPG | c.1384G>T p.E462* | Nonsense Mutation (SNP) | VAF 11/30 reads (37%) | called by muse, mutect2, varscan2
- CDCP1 | c.926T>C p.F309S | Missense Mutation (SNP) | VAF 74/313 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDCP2 | c.1190C>A p.P397H | Missense Mutation (SNP) | VAF 16/183 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.135); called by muse, mutect2
- CDK5RAP2 | c.1413del p.K471Nfs*8 | Frame Shift Del (DEL) | VAF 18/88 reads (20%) | called by mutect2, pindel, varscan2
- CEACAM16 | c.169C>T p.P57S | Missense Mutation (SNP) | VAF 93/361 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- CFD | c.472C>A p.H158N | Missense Mutation (SNP) | VAF 95/414 reads (23%) | SIFT tolerated (0.61); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CHAMP1 | c.460C>A p.L154M | Missense Mutation (SNP) | VAF 43/252 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- CHD3 | c.1618del p.R540Vfs*16 | Frame Shift Del (DEL) | VAF 90/358 reads (25%) | called by mutect2, pindel, varscan2
- CHD4 | c.2796dup p.L933Tfs*3 (on ENST00000357008 / NM_001363606.2; = p.L946Tfs*3 on NM_001273.5) | Frame Shift Ins (INS) | VAF 24/104 reads (23%) | called by mutect2, varscan2
- CHD8 | c.5585del p.P1862Qfs*29 (on ENST00000646647 / NM_001170629.2; = p.P1583Qfs*29 on NM_020920.4) | Frame Shift Del (DEL) | VAF 53/221 reads (24%) | called by mutect2, pindel, varscan2
- CHD9 | c.1744del p.T582Qfs*7 | Frame Shift Del (DEL) | VAF 28/96 reads (29%) | called by mutect2, pindel
- CIAO2B | c.355del p.V119Cfs*14 | Frame Shift Del (DEL) | VAF 19/133 reads (14%) | called by mutect2, pindel, varscan2
- CLTC | c.209G>A p.S70N | Missense Mutation (SNP) | VAF 30/369 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.914); called by muse, mutect2
- CNDP2 | c.871G>A p.V291M | Missense Mutation (SNP) | VAF 35/154 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.442); called by muse, mutect2, varscan2
- CNGA1 | c.2045C>A p.P682H | Missense Mutation (SNP) | VAF 36/386 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.533); called by muse, mutect2
- CNOT1 | c.6280G>A p.G2094S | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- CNOT9 | c.356del p.L119Cfs*29 | Frame Shift Del (DEL) | VAF 87/270 reads (32%) | called by mutect2, pindel, varscan2
- COL18A1 | c.2097_2098insA p.L700Ifs*13 (on ENST00000359759 / NM_130444.3; = p.L465Ifs*13 on NM_030582.4) | Frame Shift Ins (INS) | VAF 39/375 reads (10%) | called by mutect2, pindel, varscan2
- COL5A2 | c.2950G>A p.G984S | Missense Mutation (SNP) | VAF 49/210 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COL6A3 | c.4770del p.R1591Dfs*15 | Frame Shift Del (DEL) | VAF 38/262 reads (15%) | called by pindel, varscan2
- CORO1C | c.1217A>T p.K406M | Missense Mutation (SNP) | VAF 134/553 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- CORO7 | c.1682C>T p.A561V | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- CPO | c.615T>G p.C205W | Missense Mutation (SNP) | VAF 82/285 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CRAT | c.1867del p.R623Gfs*47 | Frame Shift Del (DEL) | VAF 44/195 reads (23%) | called by mutect2, pindel, varscan2
- CRB1 | c.1346A>G p.Q449R | Missense Mutation (SNP) | VAF 20/478 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.174); called by muse, mutect2
- CRTC2 | c.872del p.L291Rfs*11 | Frame Shift Del (DEL) | VAF 42/155 reads (27%) | called by mutect2, pindel, varscan2
- CRYM | c.533C>T p.A178V | Missense Mutation (SNP) | VAF 61/248 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- CRYM | c.326T>C p.V109A | Missense Mutation (SNP) | VAF 36/350 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.125); called by muse, mutect2
- CSF3 | c.97del p.L33Wfs*16 | Frame Shift Del (DEL) | VAF 17/76 reads (22%) | called by mutect2, pindel, varscan2
- CSTF3 | c.2131C>T p.R711W | Missense Mutation (SNP) | VAF 26/182 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CTPS1 | c.1560dup p.V521Cfs*8 | Frame Shift Ins (INS) | VAF 12/59 reads (20%) | called by pindel, varscan2
- CUBN | c.122+2T>C p.X41_splice | Splice Site (SNP) | VAF 24/416 reads (6%) | called by muse, mutect2
- CUL4A | c.949C>T p.P317S (on ENST00000375440 / NM_001008895.4; = p.P217S on NM_003589.3) | Missense Mutation (SNP) | VAF 24/310 reads (8%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2
- CUX1 | c.1762G>A p.E588K | Missense Mutation (SNP) | VAF 17/399 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- CUX1 | c.4373G>A p.S1458N | Missense Mutation (SNP) | VAF 7/97 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); called by muse, mutect2
- CXCR5 | c.569T>A p.V190D | Missense Mutation (SNP) | VAF 35/237 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CYP4F24P | n.468C>T | Splice Region (SNP) | VAF 9/153 reads (6%) | called by muse, mutect2
- DACH1 | c.1039dup p.I347Nfs*13 | Frame Shift Ins (INS) | VAF 14/114 reads (12%) | called by mutect2, varscan2
- DACH2 | c.203G>A p.C68Y | Missense Mutation (SNP) | VAF 50/191 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DDX6 | c.353dup p.P119Afs*16 | Frame Shift Ins (INS) | VAF 12/85 reads (14%) | called by mutect2, pindel, varscan2
- DENND4A | c.5479A>G p.M1827V | Missense Mutation (SNP) | VAF 9/161 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, mutect2
- DHRS4L2 | c.529_531del p.P177del | In Frame Del (DEL) | VAF 28/165 reads (17%) | called by mutect2, varscan2
- DHRS7B | c.890C>T p.A297V | Missense Mutation (SNP) | VAF 29/518 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.102); called by muse, mutect2
- DHX35 | c.581del p.K194Rfs*11 | Frame Shift Del (DEL) | VAF 24/151 reads (16%) | called by mutect2, varscan2
- DICER1 | c.5604-5del | Splice Region (DEL) | VAF 50/367 reads (14%) | called by pindel, varscan2
- DLGAP2 | c.1065G>T p.E355D | Missense Mutation (SNP) | VAF 66/247 reads (27%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- DMBT1 | c.5737G>A p.A1913T (on ENST00000338354 / NM_001377530.1; = p.A1156T on NM_004406.3) | Missense Mutation (SNP) | VAF 57/265 reads (22%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- DMRTA2 | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 16/177 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- DNAAF1 | c.1091A>G p.E364G | Missense Mutation (SNP) | VAF 128/423 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- DNAH17 | c.12500C>T p.T4167I | Missense Mutation (SNP) | VAF 86/356 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- DNAJA1 | c.280G>T p.G94* | Nonsense Mutation (SNP) | VAF 15/315 reads (5%) | called by muse, mutect2
- DNMT1 | c.2021T>G p.V674G | Missense Mutation (SNP) | VAF 63/579 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- DOCK1 | c.2583del p.M862* | Frame Shift Del (DEL) | VAF 85/434 reads (20%) | called by mutect2, pindel, varscan2
- DRGX | c.593G>A p.C198Y | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- DSCAM | c.1693C>T p.Q565* | Nonsense Mutation (SNP) | VAF 16/357 reads (4%) | called by muse, mutect2
- DTD1 | c.412G>A p.D138N | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.744); called by muse, mutect2
- DYNC2I1 | c.52C>A p.L18I | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- DZIP3 | c.2983G>A p.A995T | Missense Mutation (SNP) | VAF 62/219 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- E2F3 | c.901T>C p.Y301H | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- ECM1 | c.1564del p.E522Sfs*45 | Frame Shift Del (DEL) | VAF 69/256 reads (27%) | called by mutect2, pindel, varscan2
- EEF2K | c.386T>G p.V129G | Missense Mutation (SNP) | VAF 67/228 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- EFHC1 | c.1067_1068del p.K356Rfs*7 | Frame Shift Del (DEL) | VAF 78/280 reads (28%) | called by mutect2, pindel, varscan2
- EHD1 | c.1409A>T p.E470V | Missense Mutation (SNP) | VAF 130/469 reads (28%) | SIFT tolerated (0.62); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- EHF | c.187_189del p.L63del | In Frame Del (DEL) | VAF 43/155 reads (28%) | called by mutect2, pindel, varscan2
- ELFN2 | c.941T>C p.I314T | Missense Mutation (SNP) | VAF 30/193 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- ELOF1 | c.169T>C p.F57L | Missense Mutation (SNP) | VAF 18/382 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); called by muse, mutect2
- EPHA2 | c.719del p.G240Vfs*153 | Frame Shift Del (DEL) | VAF 32/394 reads (8%) | called by mutect2, pindel
- EPHA5 | c.696del p.K232Nfs*36 | Frame Shift Del (DEL) | VAF 16/166 reads (10%) | called by mutect2, pindel
- EPHA7 | c.734C>T p.A245V | Missense Mutation (SNP) | VAF 62/248 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ESPL1 | c.3886C>T p.P1296S | Missense Mutation (SNP) | VAF 22/236 reads (9%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.962); called by muse, mutect2
- EXOC8 | c.434del p.G145Vfs*45 | Frame Shift Del (DEL) | VAF 78/301 reads (26%) | called by mutect2, pindel, varscan2
- EYA2 | c.1226C>T p.T409I | Missense Mutation (SNP) | VAF 18/152 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.87); called by muse, mutect2
- FAM135B | c.156A>G p.T52= | Splice Region (SNP) | VAF 34/150 reads (23%) | called by muse, mutect2, varscan2
- FAM214A | c.1367C>A p.T456N | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- FAT2 | c.10325G>A p.G3442D | Missense Mutation (SNP) | VAF 33/312 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FIZ1 | c.1150G>T p.G384C | Missense Mutation (SNP) | VAF 48/165 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FOXL1 | c.984dup p.F329Lfs*35 | Frame Shift Ins (INS) | VAF 14/166 reads (8%) | called by mutect2, pindel
- G2E3 | c.283G>A p.A95T | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- GABRB3 | c.508del p.L170Wfs*66 | Frame Shift Del (DEL) | VAF 118/426 reads (28%) | called by mutect2, varscan2
- GALNS | c.1360del p.L454Sfs*41 | Frame Shift Del (DEL) | VAF 75/352 reads (21%) | called by mutect2, pindel, varscan2
- GCSAML | c.331G>T p.A111S | Missense Mutation (SNP) | VAF 84/306 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.668); called by muse, varscan2
- GGA1 | c.1657del p.Q553Sfs*16 | Frame Shift Del (DEL) | VAF 36/148 reads (24%) | called by mutect2, pindel, varscan2
- GLT1D1 | c.68G>T p.R23L | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- GPR176 | c.704G>A p.S235N | Missense Mutation (SNP) | VAF 41/216 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GTF3C2 | c.677_679del p.K226del | In Frame Del (DEL) | VAF 51/244 reads (21%) | called by pindel, varscan2
- GUCY1A2 | c.1673G>A p.G558E | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, varscan2
- GYS1 | c.2081C>T p.P694L | Missense Mutation (SNP) | VAF 32/344 reads (9%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); called by muse, mutect2
- HAS1 | c.1441G>A p.V481I | Missense Mutation (SNP) | VAF 66/278 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- HCN1 | c.1543A>G p.I515V | Missense Mutation (SNP) | VAF 24/388 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.631); called by muse, mutect2
- HDX | c.500T>C p.L167P | Missense Mutation (SNP) | VAF 9/126 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.58); called by muse, mutect2
- HECTD2 | c.1094+1G>A p.X365_splice | Splice Site (SNP) | VAF 11/39 reads (28%) | called by muse, mutect2, varscan2
- HHEX | c.147del p.T50Rfs*58 | Frame Shift Del (DEL) | VAF 40/281 reads (14%) | called by mutect2, pindel, varscan2
- HMGB2 | c.218G>T p.R73M | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- HMX1 | c.300del p.G101Vfs*124 | Frame Shift Del (DEL) | VAF 9/43 reads (21%) | called by mutect2, pindel, varscan2
- HOXA4 | c.262G>A p.A88T | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2
- HOXB3 | c.1172del p.P391Lfs*38 | Frame Shift Del (DEL) | VAF 19/184 reads (10%) | called by mutect2, pindel
- HOXB3 | c.1094del p.P365Lfs*64 | Frame Shift Del (DEL) | VAF 14/70 reads (20%) | called by mutect2, pindel, varscan2
- HSF1 | c.1347del p.R450Gfs*66 | Frame Shift Del (DEL) | VAF 12/134 reads (9%) | called by mutect2, pindel
- HSP90AB1 | c.1916G>A p.R639Q | Missense Mutation (SNP) | VAF 79/380 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- HSPA12A | c.1356del p.F452Lfs*88 | Frame Shift Del (DEL) | VAF 55/267 reads (21%) | called by mutect2, pindel, varscan2
- HSPB8 | c.266del p.P89Hfs*12 | Frame Shift Del (DEL) | VAF 29/132 reads (22%) | called by mutect2, pindel
- HTATIP2 | c.370T>C p.C124R | Missense Mutation (SNP) | VAF 55/231 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- HTR2A | c.1293T>A p.N431K | Missense Mutation (SNP) | VAF 53/200 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- HYDIN | c.11662C>T p.Q3888* | Nonsense Mutation (SNP) | VAF 28/299 reads (9%) | called by muse, mutect2, varscan2
- ICAM3 | c.213G>T p.K71N | Missense Mutation (SNP) | VAF 21/456 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- IDE | c.786A>G p.E262= | Splice Region (SNP) | VAF 6/28 reads (21%) | called by muse, mutect2, varscan2
- IFI44L | c.1298del p.L433* | Frame Shift Del (DEL) | VAF 28/141 reads (20%) | called by mutect2, pindel, varscan2
- IFT81 | c.830T>C p.V277A | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- IKZF4 | c.1388A>G p.H463R | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.192); called by muse, mutect2
- IL13RA1 | c.1075G>A p.A359T | Missense Mutation (SNP) | VAF 54/228 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- IL1RAPL1 | c.377G>A p.C126Y | Missense Mutation (SNP) | VAF 24/182 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IL1RAPL1 | c.1372A>G p.T458A | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- IMMT | c.1354G>A p.A452T | Missense Mutation (SNP) | VAF 111/393 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.657); called by muse, mutect2, varscan2
- INPP4A | c.1850del p.P617Lfs*18 (on ENST00000074304 / NM_001134224.1; = p.P578Lfs*18 on NM_001566.2 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 45/191 reads (24%) | called by mutect2, pindel, varscan2
- INSM2 | c.875G>A p.R292H | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IQGAP2 | c.272dup p.I92Dfs*3 | Frame Shift Ins (INS) | VAF 14/135 reads (10%) | called by pindel, varscan2
- IQSEC2 | c.533C>T p.A178V | Missense Mutation (SNP) | VAF 21/246 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.972); called by muse, mutect2
- ITGA4 | c.1000A>G p.R334G | Missense Mutation (SNP) | VAF 55/221 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITGA9 | c.308C>T p.A103V | Missense Mutation (SNP) | VAF 116/540 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- JARID2 | c.2028del p.K676Nfs*5 | Frame Shift Del (DEL) | VAF 14/171 reads (8%) | called by mutect2, pindel
- JPH1 | c.944G>A p.G315E | Missense Mutation (SNP) | VAF 37/712 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KCNH3 | c.2652G>A p.A884= | Splice Region (SNP) | VAF 47/170 reads (28%) | called by muse, mutect2, varscan2
- KCTD18 | c.77G>A p.R26Q | Missense Mutation (SNP) | VAF 8/189 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2
- KCTD3 | c.133del p.S45Pfs*4 | Frame Shift Del (DEL) | VAF 8/32 reads (25%) | called by mutect2, varscan2
- KHDC1 | c.52G>A p.V18I | Missense Mutation (SNP) | VAF 20/287 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); called by muse, mutect2
- KIAA1755 | c.2672A>G p.Q891R | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.194); called by muse, mutect2
- KIF13B | c.1397A>G p.Y466C | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- KIF1A | c.4639C>T p.P1547S (on ENST00000320389 / NM_001379639.1; = p.P1539S on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/230 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIF26B | c.5263del p.T1755Pfs*121 | Frame Shift Del (DEL) | VAF 27/76 reads (36%) | called by mutect2, pindel, varscan2
- KIF4A | c.265C>T p.Q89* | Nonsense Mutation (SNP) | VAF 18/345 reads (5%) | called by muse, mutect2
- KLHL20 | c.1789G>T p.G597* | Nonsense Mutation (SNP) | VAF 69/176 reads (39%) | called by muse, mutect2, varscan2
- KLK4 | c.679C>A p.P227T | Missense Mutation (SNP) | VAF 66/480 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- KMT2D | c.7061del p.P2354Lfs*30 | Frame Shift Del (DEL) | VAF 47/199 reads (24%) | called by mutect2, pindel, varscan2
- LAMC3 | c.2096del p.G699Vfs*185 | Frame Shift Del (DEL) | VAF 52/473 reads (11%) | called by mutect2, varscan2
- LARGE1 | c.512A>G p.H171R | Missense Mutation (SNP) | VAF 109/442 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LEXM | c.967T>C p.C323R | Missense Mutation (SNP) | VAF 29/232 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- LMNB2 | c.646C>T p.Q216* | Nonsense Mutation (SNP) | VAF 60/567 reads (11%) | called by muse, mutect2
- LONRF3 | c.386G>A p.G129D | Missense Mutation (SNP) | VAF 86/367 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- LOXHD1 | c.55T>C p.Y19H | Missense Mutation (SNP) | VAF 25/267 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.095); called by muse, mutect2
- LRIG1 | c.2479G>A p.V827I | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.58); PolyPhen benign (0.145); called by muse, mutect2
- LRP5 | c.1843C>A p.L615M | Missense Mutation (SNP) | VAF 12/244 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LRRCC1 | c.1057dup p.I353Nfs*4 | Frame Shift Ins (INS) | VAF 10/48 reads (21%) | called by mutect2, pindel
- MACF1 | c.16991A>G p.D5664G (on ENST00000372915; = p.D3706G on NM_012090.5) | Missense Mutation (SNP) | VAF 40/329 reads (12%) | called by muse, varscan2
- MAGEH1 | c.67C>A p.R23S | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- MAGEL2 | c.1923del p.L642Wfs*60 | Frame Shift Del (DEL) | VAF 33/156 reads (21%) | called by mutect2, pindel, varscan2
- MAP11 | c.769C>T p.R257* | Nonsense Mutation (SNP) | VAF 17/132 reads (13%) | called by muse, mutect2, varscan2
- MAP2K7 | c.1229T>C p.L410P | Missense Mutation (SNP) | VAF 19/227 reads (8%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.202); called by muse, mutect2
- MAT1A | c.661G>A p.A221T | Missense Mutation (SNP) | VAF 173/616 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MATN3 | c.928T>C p.C310R | Missense Mutation (SNP) | VAF 12/231 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.037); called by muse, mutect2
- MATR3 | c.-489_-488del | Splice Site (DEL) | VAF 104/468 reads (22%) | called by pindel, varscan2
- MBTPS1 | c.259A>T p.I87F | Missense Mutation (SNP) | VAF 21/301 reads (7%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.959); called by muse, mutect2
- MCM5 | c.680T>C p.L227P | Missense Mutation (SNP) | VAF 17/214 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- MEX3B | c.1595C>A p.P532H | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MLPH | c.1649A>G p.K550R | Missense Mutation (SNP) | VAF 78/329 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.161); called by muse, mutect2, varscan2
- MMAB | c.547C>T p.H183Y | Missense Mutation (SNP) | VAF 83/646 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MOGS | c.1559C>T p.A520V | Missense Mutation (SNP) | VAF 82/343 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MROH2B | c.2564A>C p.K855T | Missense Mutation (SNP) | VAF 42/158 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- MSI1 | c.361A>G p.T121A | Missense Mutation (SNP) | VAF 26/256 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- MUC16 | c.23136del p.S7713Lfs*5 | Frame Shift Del (DEL) | VAF 8/78 reads (10%) | called by mutect2, varscan2
- MVB12B | c.821C>A p.P274H | Missense Mutation (SNP) | VAF 35/166 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- MYH1 | c.879G>A p.M293I | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MYH10 | c.5894G>T p.S1965I | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.042); called by muse, mutect2
- MYH11 | c.1676G>A p.S559N | Missense Mutation (SNP) | VAF 18/432 reads (4%) | SIFT tolerated (0.55); PolyPhen benign (0.003); called by muse, mutect2
- MYH7 | c.227T>C p.V76A | Missense Mutation (SNP) | VAF 59/400 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- MYO15B | c.5122del p.A1708Pfs*79 | Frame Shift Del (DEL) | VAF 8/70 reads (11%) | called by mutect2, pindel, varscan2
- MYO18A | c.3739A>G p.I1247V | Missense Mutation (SNP) | VAF 42/181 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MYO5C | c.5014T>A p.S1672T | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- MYO7B | c.2296G>A p.A766T | Missense Mutation (SNP) | VAF 75/297 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.577); called by muse, mutect2, varscan2
- NBEAL2 | c.8027+1G>A p.X2676_splice | Splice Site (SNP) | VAF 24/326 reads (7%) | called by muse, mutect2
- NCOA2 | c.3877dup p.Q1293Pfs*20 | Frame Shift Ins (INS) | VAF 56/257 reads (22%) | called by mutect2, pindel, varscan2
- NDUFS8 | c.163G>A p.A55T | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.022); called by muse, mutect2
- NEB | c.12673G>T p.G4225C | Missense Mutation (SNP) | VAF 13/209 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NEK8 | c.1091G>A p.G364D | Missense Mutation (SNP) | VAF 19/298 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.224); called by muse, mutect2
- NELL1 | c.1772G>A p.G591E | Missense Mutation (SNP) | VAF 38/139 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.75); called by muse, mutect2, varscan2
- NEURL4 | c.2299C>T p.Q767* | Nonsense Mutation (SNP) | VAF 21/304 reads (7%) | called by muse, mutect2
- NFATC4 | c.1705del p.Q569Rfs*30 | Frame Shift Del (DEL) | VAF 99/420 reads (24%) | called by pindel, varscan2
- NFS1 | c.808_814del p.I270Afs*29 | Frame Shift Del (DEL) | VAF 27/160 reads (17%) | called by mutect2, pindel, varscan2
- NHS | c.848del p.L283* | Frame Shift Del (DEL) | VAF 113/511 reads (22%) | called by mutect2, pindel, varscan2
- NKX3-2 | c.362del p.G121Dfs*3 | Frame Shift Del (DEL) | VAF 10/46 reads (22%) | called by pindel, varscan2
- NKX3-2 | c.344G>T p.G115V | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.629); called by muse, varscan2
- NKX6-2 | c.146G>A p.G49D | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.018); called by muse, mutect2
- NLRC5 | c.1657G>T p.A553S | Missense Mutation (SNP) | VAF 28/387 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.028); called by muse, mutect2
- NLRP6 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 11/62 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- NME9 | c.506C>T p.A169V (on ENST00000333911 / NM_001349024.2; = p.A108V on NM_178130.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/157 reads (10%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.99); called by muse, mutect2
- NOL6 | c.2594A>G p.Q865R | Missense Mutation (SNP) | VAF 18/250 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- NOL6 | c.1916del p.G639Afs*10 | Frame Shift Del (DEL) | VAF 9/108 reads (8%) | called by mutect2, pindel
- NOVA1 | c.1282G>A p.V428M | Missense Mutation (SNP) | VAF 71/327 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NOX4 | c.7G>A p.V3M | Missense Mutation (SNP) | VAF 33/162 reads (20%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NPC1 | c.1649A>T p.Y550F | Missense Mutation (SNP) | VAF 47/524 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.029); called by muse, mutect2
- NUCB2 | c.109A>G p.I37V | Missense Mutation (SNP) | VAF 14/137 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR7A10 | c.542T>A p.I181N | Missense Mutation (SNP) | VAF 78/255 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.732); called by muse, mutect2, varscan2
- OR8B3 | c.708del p.A237Pfs*55 | Frame Shift Del (DEL) | VAF 26/79 reads (33%) | called by mutect2, varscan2
- OSBPL8 | c.1280C>T p.T427I | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- P4HA3 | c.1210G>T p.V404L | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT tolerated (0.62); PolyPhen benign (0.053); called by muse, mutect2
- PAGE3 | c.286C>T p.P96S | Missense Mutation (SNP) | VAF 12/305 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.815); called by muse, mutect2
- PATJ | c.851A>C p.D284A | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by mutect2, varscan2
- PCDH19 | c.776G>A p.R259H | Missense Mutation (SNP) | VAF 50/196 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PCDHGA12 | c.1990G>A p.V664M | Missense Mutation (SNP) | VAF 142/565 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.532); called by muse, mutect2, varscan2
- PCMTD2 | c.1001del p.P334Qfs*2 | Frame Shift Del (DEL) | VAF 25/74 reads (34%) | called by mutect2, pindel, varscan2
- PCNX3 | c.3400T>C p.F1134L | Missense Mutation (SNP) | VAF 16/213 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2
- PDYN | c.277A>G p.S93G | Missense Mutation (SNP) | VAF 45/400 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- PFKL | c.1844T>C p.M615T | Missense Mutation (SNP) | VAF 13/265 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2
- PHF1 | c.641C>T p.A214V | Missense Mutation (SNP) | VAF 9/166 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- PIGR | c.837_838del p.C279* | Nonsense Mutation (DEL) | VAF 12/105 reads (11%) | called by pindel, varscan2
- PIWIL3 | c.1333G>T p.D445Y | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- PJA2 | c.73G>A p.A25T | Missense Mutation (SNP) | VAF 16/321 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.395); called by muse, mutect2
- PLXNA3 | c.3163C>T p.R1055W | Missense Mutation (SNP) | VAF 22/270 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2
- PLXNC1 | c.3016G>A p.V1006M | Missense Mutation (SNP) | VAF 15/192 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.435); called by muse, mutect2
- PMPCA | c.761C>T p.A254V | Missense Mutation (SNP) | VAF 13/156 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.817); called by muse, mutect2
- PNRC1 | c.752del p.K251Sfs*14 | Frame Shift Del (DEL) | VAF 26/179 reads (15%) | called by mutect2, pindel, varscan2
- POLD1 | c.137C>T p.A46V | Missense Mutation (SNP) | VAF 26/271 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, mutect2
- POLN | c.2621C>T p.P874L | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- POLR3B | c.2806T>C p.S936P | Missense Mutation (SNP) | VAF 186/653 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PREX2 | c.4051del p.Y1351Tfs*27 | Frame Shift Del (DEL) | VAF 4/35 reads (11%) | called by mutect2, pindel
- PRKCB | c.1613A>G p.Q538R | Missense Mutation (SNP) | VAF 48/152 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- PRKCI | c.171G>A p.M57I | Missense Mutation (SNP) | VAF 28/230 reads (12%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRMT2 | c.856del p.S286Qfs*9 | Frame Shift Del (DEL) | VAF 12/115 reads (10%) | called by mutect2, pindel, varscan2
- PROB1 | c.1766C>T p.P589L | Missense Mutation (SNP) | VAF 37/187 reads (20%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PROX1 | c.225G>T p.K75N | Missense Mutation (SNP) | VAF 15/130 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PRR14 | c.836del p.P279Qfs*2 | Frame Shift Del (DEL) | VAF 23/96 reads (24%) | called by mutect2, pindel
- PRR14L | c.2017C>T p.H673Y | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRR35 | c.336del p.A113Rfs*190 | Frame Shift Del (DEL) | VAF 25/200 reads (13%) | called by mutect2, pindel, varscan2
- PSD4 | c.1181_1182del p.L394Qfs*3 | Frame Shift Del (DEL) | VAF 44/162 reads (27%) | called by pindel, varscan2
- PTCH1 | c.3606del p.S1203Afs*52 | Frame Shift Del (DEL) | VAF 72/346 reads (21%) | called by mutect2, varscan2
- PTEN | c.867del p.V290* | Frame Shift Del (DEL) | VAF 23/106 reads (22%) | called by mutect2, varscan2
- PTF1A | c.682G>A p.G228S | Missense Mutation (SNP) | VAF 25/157 reads (16%) | SIFT tolerated (0.95); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTGES3L-AARSD1 | c.1154A>G p.H385R (on ENST00000421990 / NM_001136042.2; = p.H367R on NM_025267.3) | Missense Mutation (SNP) | VAF 41/162 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.274); called by muse, mutect2, varscan2
- PTPN23 | c.2874_2879del p.H958_P959del | In Frame Del (DEL) | VAF 12/126 reads (10%) | called by mutect2, pindel
- PTPRO | c.3026C>T p.A1009V (on ENST00000281171 / NM_030667.3; = p.A981V on NM_002848.4) | Missense Mutation (SNP) | VAF 46/482 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- PTPRZ1 | c.1690del p.S564Lfs*2 | Frame Shift Del (DEL) | VAF 35/127 reads (28%) | called by mutect2, pindel, varscan2
- PUM3 | c.1752T>G p.H584Q | Missense Mutation (SNP) | VAF 12/224 reads (5%) | SIFT tolerated (0.61); PolyPhen benign (0.003); called by muse, mutect2
- PUS10 | c.455T>C p.L152P | Missense Mutation (SNP) | VAF 37/175 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- PXDN | c.3179G>A p.G1060D | Missense Mutation (SNP) | VAF 32/468 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.962); called by muse, mutect2
- QSER1 | c.4757G>A p.G1586D (on ENST00000399302; = p.G1715D on NM_001076786.3) | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); called by muse, mutect2, varscan2
- RAPGEF2 | c.1564del p.S522Vfs*12 | Frame Shift Del (DEL) | VAF 55/247 reads (22%) | called by mutect2, pindel, varscan2
- RBM12 | c.1595T>C p.I532T | Missense Mutation (SNP) | VAF 28/238 reads (12%) | SIFT tolerated (0.64); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RELL2 | c.124_126del p.K42del | In Frame Del (DEL) | VAF 33/142 reads (23%) | called by pindel, varscan2
- REXO1 | c.235del p.E79Rfs*81 | Frame Shift Del (DEL) | VAF 43/208 reads (21%) | called by mutect2, pindel, varscan2
- RGS7 | c.970C>T p.Q324* | Nonsense Mutation (SNP) | VAF 32/387 reads (8%) | called by muse, mutect2
- RGS9 | c.1645_1646insA p.R549Qfs*27 | Frame Shift Ins (INS) | VAF 56/217 reads (26%) | called by mutect2, pindel, varscan2
- RNF123 | c.3107A>G p.Q1036R | Missense Mutation (SNP) | VAF 22/280 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); called by muse, mutect2
525 further variants in this file (122 protein-altering or splice-affecting, 226 silent, 177 other) are not listed here.
